Somatic mutation profile of tumor specimen TCGA-AU-6004-01A (aliquot TCGA-AU-6004-01A-11D-1719-10) from TCGA case TCGA-AU-6004, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage I; Age at diagnosis: 69.2 years (25,259 days).
Specimen TCGA-AU-6004-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b49d2af-b239-410b-a4e2-17983328028d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AU-6004-10A (Blood Derived Normal), aliquot TCGA-AU-6004-10A-01D-1719-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a67a74e6-9b3e-4d9b-a4fc-a78eb7122022

The open-access MAF lists 1,162 somatic variants for this specimen: 900 protein-altering or splice-affecting, 239 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 587, Silent 239, Frame Shift Del 192, Frame Shift Ins 56, Nonsense Mutation 28, Splice Site 16, In Frame Del 11, Splice Region 9, RNA 9, Intron 8, 3'UTR 2, 5'Flank 2.

Variants (750 of 1,162; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AR | c.1789G>A p.A597T | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs137852569, CM920071, COSV65954647; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP2A1 | c.2464dup p.R822Pfs*39 | Frame Shift Ins (INS) | VAF 32/164 reads (20%) | catalogued as rs751365374; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- COL1A1 | c.2596G>A p.G866S | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs67445413, CM011293, CM990379, COSV56810016; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL5A1 | c.2988del p.G997Afs*77 | Frame Shift Del (DEL) | VAF 32/161 reads (20%) | catalogued as rs764693725; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KCNQ2 | c.1621A>G p.R541G (on ENST00000359125 / NM_172107.4; = p.R513G on NM_004518.6) | Missense Mutation (SNP) | VAF 93/374 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555853971, CM156000, COSV60555235; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MCPH1 | c.321del p.K107Nfs*39 | Frame Shift Del (DEL) | VAF 24/132 reads (18%) | catalogued as rs759663956; ClinVar: pathogenic; called by mutect2, varscan2
- MECP2 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 64/314 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as rs28934908, CM003325, COSV57653043; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MFRP | chr11:119345563 del G | 5'Flank (DEL) | VAF 12/81 reads (15%) | catalogued as rs587776596, CD052468, COSV64129114; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NPC1 | c.2713C>T p.Q905* | Nonsense Mutation (SNP) | VAF 29/160 reads (18%) | catalogued as rs917070773, COSV52584156; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 31/177 reads (18%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RUNX2 | c.90del p.S31Pfs*9 | Frame Shift Del (DEL) | VAF 58/272 reads (21%) | catalogued as rs397515538; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SLCO2A1 | c.830del p.F277Sfs*8 | Frame Shift Del (DEL) | VAF 13/61 reads (21%) | catalogued as rs751192029; ClinVar: pathogenic; called by mutect2, varscan2
- TUBA1A | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 42/212 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as rs886039513, CM145649, COSV55497204; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.2607del p.T871Lfs*13 | Frame Shift Del (DEL) | VAF 22/56 reads (39%) | catalogued as rs771808127, COSV55113098; called by mutect2, varscan2
- AASS | c.1255C>T p.L419F | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62792149; called by muse, mutect2, varscan2
- ABCC4 | c.1339G>A p.V447M | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1345176162, COSV65311190; called by muse, mutect2, varscan2
- ABCC6 | c.950G>A p.S317N | Missense Mutation (SNP) | VAF 46/201 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as rs749267111, COSV99229741; called by muse, varscan2
- ABLIM3 | c.1601G>A p.R534Q | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.9); catalogued as rs373620710, COSV100448778, COSV58644797; called by muse, mutect2, varscan2
- ABTB1 | c.367G>T p.G123W | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51743124; called by muse, mutect2, varscan2
- ACAD9 | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781156571, CM153911, COSV58310296; called by muse, mutect2, varscan2
- ACE2 | c.1837T>C p.Y613H | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.965); catalogued as COSV53027986; called by muse, mutect2, varscan2
- ACIN1 | c.3359del p.P1120Hfs*110 | Frame Shift Del (DEL) | VAF 37/157 reads (24%) | catalogued as rs756288275; called by mutect2, pindel, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 81/187 reads (43%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM19 | c.2161T>C p.Y721H | Missense Mutation (SNP) | VAF 78/277 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.339); catalogued as COSV57434808; called by muse, mutect2, varscan2
- ADAMTS13 | c.3493C>T p.R1165W | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs587664518, COSV52468647, COSV99390239; called by muse, varscan2
- ADAMTS18 | c.3584G>C p.C1195S | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51423770; called by muse, mutect2, varscan2
- ADAMTS2 | c.2072G>A p.R691H | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs201052588; called by muse, mutect2
- ADAMTS3 | c.3565G>A p.G1189R | Missense Mutation (SNP) | VAF 95/585 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.073); catalogued as COSV54393799; called by muse, mutect2, varscan2
- ADAMTS3 | c.1349T>A p.I450N | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54404258; called by muse, mutect2, varscan2
- ADAMTS7 | c.4015A>G p.T1339A | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.024); catalogued as COSV101183293; called by muse, mutect2
- ADCY10 | c.2917A>G p.I973V | Missense Mutation (SNP) | VAF 24/290 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as COSV63245434; called by muse, mutect2
- ADCY2 | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs968274397, COSV57874000, COSV57900327; called by muse, mutect2, varscan2
- ADGRB2 | c.2539C>T p.R847C | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57071084; called by muse, mutect2, varscan2
- ADGRD1 | c.1210G>A p.G404R | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs749195476, COSV55441948, COSV55449677; called by muse, mutect2, varscan2
- ADGRL1 | c.3970G>A p.G1324R (on ENST00000340736 / NM_001008701.3; = p.G1319R on NM_014921.5) | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0.263); catalogued as rs781735623, COSV61566889; called by muse, mutect2, varscan2
- ADSS1 | c.847G>T p.G283C | Missense Mutation (SNP) | VAF 44/227 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58276636; called by muse, mutect2, varscan2
- AFP | c.1427C>T p.A476V | Missense Mutation (SNP) | VAF 81/303 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.027); catalogued as rs376466369; called by muse, mutect2, varscan2
- AGL | c.1874C>T p.T625M | Missense Mutation (SNP) | VAF 135/504 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs147569805, COSV54059039; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AGO3 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1331817180, COSV55797591; called by muse, mutect2, varscan2
- AHNAK | c.10642A>G p.I3548V | Missense Mutation (SNP) | VAF 76/317 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as rs1335647135, COSV57232922; called by muse, mutect2, varscan2
- AHNAK2 | c.5501G>T p.G1834V | Missense Mutation (SNP) | VAF 101/494 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60932513; called by muse, varscan2
- AKAP12 | c.1670G>A p.S557N | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV53583022; called by muse, mutect2
- AKAP4 | c.942C>A p.D314E | Missense Mutation (SNP) | VAF 46/221 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs1461980948, COSV62075601; called by muse, mutect2, varscan2
- AKR1C1 | c.571-2A>G p.X191_splice | Splice Site (SNP) | VAF 142/693 reads (20%) | catalogued as COSV66500044; called by muse, mutect2, varscan2
- AL031315.1 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs201447076, COSV61216787; called by muse, mutect2, varscan2
- ALDH1A2 | c.653G>A p.S218N | Missense Mutation (SNP) | VAF 47/212 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as COSV51093637; called by muse, mutect2, varscan2
- AMPD2 | c.223-3del | Splice Region (DEL) | VAF 36/136 reads (26%) | catalogued as rs770280481; called by mutect2, varscan2
- ANGPTL6 | c.1288G>A p.G430S | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs769478685, COSV53463224; called by muse, mutect2, varscan2
- ANK3 | c.4592C>T p.T1531M | Missense Mutation (SNP) | VAF 68/386 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1415381391, COSV55051615; called by muse, mutect2, varscan2
- ANKFY1 | c.1354G>A p.A452T | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.495); catalogued as rs147745463, COSV100492449; called by muse, mutect2, varscan2
- ANKK1 | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs558913172, COSV58274560; called by muse, mutect2, varscan2
- ANKRD13B | c.1054A>G p.N352D | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.021); catalogued as COSV61472142; called by muse, mutect2, varscan2
- ANKS1A | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64464991; called by muse, mutect2, varscan2
- APEH | c.1531del p.H511Ifs*24 | Frame Shift Del (DEL) | VAF 80/398 reads (20%) | catalogued as COSV56535366; called by pindel, varscan2
- APOBEC1 | c.352C>T p.R118W | Missense Mutation (SNP) | VAF 42/204 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1353444746, COSV57550193; called by muse, mutect2, varscan2
- APPL1 | c.460del p.R154Efs*6 | Frame Shift Del (DEL) | VAF 22/80 reads (28%) | catalogued as rs749401724; called by mutect2, varscan2
- ARAP3 | c.1171del p.Q391Nfs*24 | Frame Shift Del (DEL) | VAF 28/158 reads (18%) | catalogued as rs748757285; called by mutect2, pindel, varscan2
- ARHGAP25 | c.926G>A p.S309N (on ENST00000409202 / NM_001007231.3; = p.S301N on NM_014882.3) | Missense Mutation (SNP) | VAF 103/423 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.098); catalogued as COSV54909891; called by muse, mutect2, varscan2
- ARHGAP35 | c.3949G>A p.V1317M | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV68330140, COSV68330679; called by muse, mutect2, varscan2
- ARHGEF1 | c.1649G>A p.R550H | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV61529840; called by muse, varscan2
- ARHGEF10L | c.643T>G p.Y215D | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.888); catalogued as COSV63425837; called by muse, mutect2, varscan2
- ARHGEF37 | c.1199C>T p.S400L | Missense Mutation (SNP) | VAF 108/395 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs781049357, COSV61368914; called by muse, mutect2, varscan2
- ARL11 | c.201G>T p.Q67H | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56292290; called by muse, mutect2, varscan2
- ARMC5 | c.1186G>T p.G396W | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as COSV51660271; called by muse, mutect2, varscan2
- ARMH3 | c.1919T>C p.L640P | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64238493; called by muse, mutect2, varscan2
- ARNT | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.387); catalogued as COSV62232518; called by muse, mutect2, varscan2
- ASH2L | c.1316G>A p.G439D | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51701994; called by muse, mutect2, varscan2
- ASIC3 | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as rs150462572; called by muse, mutect2
- ASXL1 | c.2535dup p.S846Qfs*5 | Frame Shift Ins (INS) | VAF 48/224 reads (21%) | catalogued as rs750170870; called by mutect2, pindel, varscan2
- ATAD2B | c.1404del p.F468Lfs*9 | Frame Shift Del (DEL) | VAF 73/348 reads (21%) | catalogued as rs866490133; called by mutect2, pindel, varscan2
- ATP10A | c.2212C>T p.H738Y | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.348); catalogued as COSV63524011; called by muse, mutect2, varscan2
- ATP2C1 | c.2278C>T p.R760C | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs150745965; called by muse, mutect2, varscan2
- ATP6V0A4 | c.779T>C p.L260S | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.207); catalogued as COSV59481077; called by muse, mutect2, varscan2
- ATP6V0D2 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 76/391 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.686); catalogued as rs1298798643, COSV53418247; called by muse, mutect2, varscan2
- ATP6V1C2 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs757975196, COSV55359178; called by muse, mutect2
- ATP7A | c.1059T>A p.S353R | Missense Mutation (SNP) | VAF 55/198 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV58454983; called by muse, mutect2, varscan2
- ATXN7L2 | c.800A>C p.Q267P | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100881366, COSV63993004; called by muse, mutect2, varscan2
- B4GALNT4 | c.2972del p.G991Vfs*71 | Frame Shift Del (DEL) | VAF 13/76 reads (17%) | catalogued as rs35951843; called by mutect2, pindel
- B4GALT5 | c.686G>A p.C229Y | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65495415; called by muse, mutect2, varscan2
- BCHE | c.1028C>A p.T343N | Missense Mutation (SNP) | VAF 87/408 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.86); catalogued as COSV52259087; called by muse, mutect2, varscan2
- BCL9 | c.2726dup p.V910Cfs*42 | Frame Shift Ins (INS) | VAF 90/368 reads (24%) | catalogued as rs1553205212; called by mutect2, varscan2
- BCL9L | c.1346del p.P449Lfs*14 | Frame Shift Del (DEL) | VAF 38/179 reads (21%) | catalogued as rs754310793, COSV52681762; called by mutect2, pindel, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 35/141 reads (25%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BCR | c.979G>A p.G327S | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV59936262; called by muse, mutect2
- BCR | c.3271G>A p.V1091M | Missense Mutation (SNP) | VAF 38/603 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs778229520, COSV100006110; called by muse, mutect2
- BDP1 | c.938dup p.L313Ffs*9 | Frame Shift Ins (INS) | VAF 92/490 reads (19%) | catalogued as rs752427670; called by mutect2, varscan2
- BFAR | c.547A>G p.T183A | Missense Mutation (SNP) | VAF 33/239 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV55494647; called by muse, mutect2, varscan2
- BHMT2 | c.848G>A p.G283E | Missense Mutation (SNP) | VAF 100/523 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1407696167, COSV54874931; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 45/206 reads (22%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BOD1L1 | c.1000A>G p.R334G | Missense Mutation (SNP) | VAF 131/536 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs748042223, COSV99240539; called by muse, varscan2
- BRD3 | c.71del p.P24Rfs*24 | Frame Shift Del (DEL) | VAF 54/209 reads (26%) | catalogued as rs763134487; called by mutect2, varscan2
- BRD8 | c.2250-3del | Splice Region (DEL) | VAF 33/122 reads (27%) | catalogued as rs749043197; called by mutect2, varscan2
- BRINP3 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs142073525, COSV100818504; called by muse, mutect2, varscan2
- BRMS1 | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs1420865742, COSV60925310; called by muse, mutect2, varscan2
- BRSK2 | c.1583T>C p.L528P | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.52); catalogued as COSV57549832; called by muse, mutect2, varscan2
- C10orf67 | c.148G>A p.A50T (on ENST00000323327; = p.A51T on NM_153714.3) | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.27); catalogued as COSV60115163; called by muse, mutect2, varscan2
- C14orf180 | c.135del p.S46Pfs*3 | Frame Shift Del (DEL) | VAF 79/433 reads (18%) | catalogued as rs761345073; called by mutect2, pindel, varscan2
- C14orf39 | c.1762del p.*588Efs*16 | Frame Shift Del (DEL) | VAF 18/47 reads (38%) | catalogued as rs780875081; called by mutect2, varscan2
- C16orf87 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 58/262 reads (22%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.811); catalogued as COSV53512939; called by muse, mutect2, varscan2
- C17orf78 | c.485_487del p.E162del | In Frame Del (DEL) | VAF 20/110 reads (18%) | catalogued as rs768249035; called by pindel, varscan2
- C1QC | c.154G>A p.G52R | Missense Mutation (SNP) | VAF 56/367 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65890114; called by muse, mutect2, varscan2
- C9orf131 | c.2462A>C p.D821A | Missense Mutation (SNP) | VAF 26/266 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV56614598; called by muse, mutect2
- CACHD1 | c.1946C>T p.T649I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as COSV99263447; called by muse, mutect2
- CACNA1E | c.3196G>A p.E1066K | Missense Mutation (SNP) | VAF 25/207 reads (12%) | SIFT tolerated (0.81); PolyPhen benign (0.053); catalogued as rs374587995; called by muse, mutect2
- CACNA2D2 | c.1564C>A p.L522M | Missense Mutation (SNP) | VAF 75/268 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV56569794; called by muse, mutect2, varscan2
- CADM3 | c.1168G>T p.G390W (on ENST00000368125 / NM_001127173.3; = p.G424W on NM_021189.5) | Missense Mutation (SNP) | VAF 56/257 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV63674794; called by muse, mutect2, varscan2
- CAMSAP2 | c.2288A>G p.H763R (on ENST00000236925 / NM_001297707.2; = p.H752R on NM_203459.3) | Missense Mutation (SNP) | VAF 53/245 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV52678486; called by muse, mutect2, varscan2
- CAMTA2 | c.2597del p.P866Lfs*9 | Frame Shift Del (DEL) | VAF 49/96 reads (51%) | catalogued as rs745547658; called by mutect2, varscan2
- CARD14 | c.1415G>A p.R472H | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as rs377226624; ClinVar: likely benign; called by muse, mutect2, varscan2
- CARD9 | c.883C>A p.Q295K | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as CM097565, COSV59999258; called by muse, mutect2, varscan2
- CARMIL1 | c.2116C>T p.R706* | Nonsense Mutation (SNP) | VAF 27/118 reads (23%) | catalogued as rs778621503, COSV61524576; called by muse, mutect2, varscan2
- CARS1 | c.1411C>T p.R471C | Missense Mutation (SNP) | VAF 90/319 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1380410478, COSV53461590, COSV99542108; called by muse, mutect2, varscan2
- CASP2 | c.718G>A p.V240I | Missense Mutation (SNP) | VAF 59/264 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as rs141615673; called by muse, mutect2, varscan2
- CASP5 | c.533del p.N178Ifs*8 | Frame Shift Del (DEL) | VAF 39/150 reads (26%) | catalogued as rs765105588; called by mutect2, varscan2
- CASZ1 | c.3709C>T p.R1237* | Nonsense Mutation (SNP) | VAF 52/177 reads (29%) | catalogued as rs370332553; called by muse, mutect2, varscan2
- CATSPER4 | c.1401del p.K467Nfs*78 | Frame Shift Del (DEL) | VAF 47/200 reads (24%) | catalogued as rs769908264; called by mutect2, varscan2
- CBFA2T2 | c.1723G>A p.V575M | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs758482628, COSV60800290; called by muse, mutect2, varscan2
- CBLC | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54326185; called by muse, mutect2, varscan2
- CBY2 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 44/186 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754097956, COSV60117363; called by muse, mutect2, varscan2
- CC2D1B | c.406_408del p.E136del | In Frame Del (DEL) | VAF 38/165 reads (23%) | catalogued as rs781549658; called by pindel, varscan2
- CCDC116 | c.542A>G p.Q181R | Missense Mutation (SNP) | VAF 39/251 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53038855; called by muse, mutect2, varscan2
- CCDC185 | c.985G>A p.G329S | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT tolerated (0.78); PolyPhen benign (0.024); catalogued as rs1173730581, COSV64822056; called by muse, mutect2, varscan2
- CCDC40 | c.2681C>T p.A894V | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs762199616, COSV66479069; called by muse, mutect2, varscan2
- CCDC73 | c.2188G>C p.V730L | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as COSV58805515; called by muse, mutect2, varscan2
- CCKBR | c.136G>T p.G46* | Nonsense Mutation (SNP) | VAF 30/124 reads (24%) | catalogued as COSV58106176; called by muse, mutect2, varscan2
- CCM2 | c.1027G>A p.G343R | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); catalogued as rs1402559290, COSV51851680; called by muse, mutect2, varscan2
- CCS | c.407A>G p.D136G | Missense Mutation (SNP) | VAF 51/183 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59580744; called by muse, mutect2, varscan2
- CD79B | c.557G>T p.S186I | Missense Mutation (SNP) | VAF 62/234 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV50078131, COSV50083959; called by muse, mutect2, varscan2
- CDH16 | c.1306G>T p.E436* | Nonsense Mutation (SNP) | VAF 49/224 reads (22%) | catalogued as COSV55335574, COSV55340120; called by muse, mutect2, varscan2
- CDH4 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.165); catalogued as rs1214490669, COSV64645713, COSV64676633; called by muse, mutect2, varscan2
- CDH8 | c.872T>G p.L291R | Missense Mutation (SNP) | VAF 57/258 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as COSV54856481, COSV54868032, COSV54899386; called by muse, mutect2, varscan2
- CEL | c.2180del p.P727Lfs*34 (on ENST00000673714; = p.P724Lfs*34 on NM_001807.6) | Frame Shift Del (DEL) | VAF 46/197 reads (23%) | catalogued as rs767577207; called by mutect2, pindel, varscan2
- CELSR1 | c.5544del p.T1849Rfs*8 | Frame Shift Del (DEL) | VAF 47/210 reads (22%) | catalogued as rs776824429; called by mutect2, pindel, varscan2
- CENPC | c.616del p.R206Gfs*2 | Frame Shift Del (DEL) | VAF 68/357 reads (19%) | catalogued as rs1325731082; called by mutect2, varscan2
- CEP120 | c.2213del p.K738Rfs*29 | Frame Shift Del (DEL) | VAF 60/273 reads (22%) | catalogued as COSV100071584; called by mutect2, pindel, varscan2
- CEP170B | c.2644G>A p.G882S (on ENST00000453495; = p.G811S on NM_015005.3) | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.18); catalogued as rs772651081, COSV69026837; called by muse, mutect2, varscan2
- CEP57 | c.1480A>G p.S494G | Missense Mutation (SNP) | VAF 78/346 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV57690776; called by muse, mutect2, varscan2
- CFAP54 | c.7833del p.Q2612Rfs*5 | Frame Shift Del (DEL) | VAF 24/99 reads (24%) | catalogued as COSV100733086, COSV61573580; called by mutect2, pindel, varscan2
- CHD5 | c.2551C>T p.R851C | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1372942526, COSV52426310; called by muse, mutect2, varscan2
- CHD7 | c.8803G>A p.E2935K | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.058); catalogued as rs745944842, CM090042, COSV71115041; called by muse, mutect2, varscan2
- CHD8 | c.1789G>T p.E597* (on ENST00000646647 / NM_001170629.2; = p.E318* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 58/934 reads (6%) | catalogued as rs1555316526, COSV101303227; called by muse, mutect2
- CHRDL2 | c.985A>G p.T329A | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV55225547; called by muse, mutect2, varscan2
- CHRNA4 | c.757C>A p.P253T | Missense Mutation (SNP) | VAF 47/221 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64721299; called by muse, mutect2, varscan2
- CHST10 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV51807910; called by muse, mutect2, varscan2
- CIAO3 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs778827784, COSV52405226; called by muse, mutect2, varscan2
- CLCA2 | c.2209C>T p.R737* | Nonsense Mutation (SNP) | VAF 48/183 reads (26%) | catalogued as rs752431019, COSV65288735, COSV65288950; called by muse, mutect2, varscan2
- CLCF1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.566); catalogued as rs761887384, COSV56861697, COSV56862732; called by muse, mutect2
- CLDN10 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV54826480; called by muse, mutect2, varscan2
- CLEC2B | c.368G>A p.C123Y | Missense Mutation (SNP) | VAF 52/227 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV57310779, COSV99947069; called by muse, mutect2, varscan2
- CLIP2 | c.71C>A p.S24Y | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as COSV56287036; called by muse, mutect2
- CLRN1 | c.404T>C p.L135P (on ENST00000327047 / NM_174878.3; = p.L59P on NM_052995.2) | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV55807056; called by muse, mutect2, varscan2
- CLSTN2 | c.2258G>A p.R753H | Missense Mutation (SNP) | VAF 51/213 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs200855654, COSV71725274; called by muse, mutect2, varscan2
- CMKLR1 | c.609G>A p.W203* (on ENST00000312143 / NM_001142344.2; = p.W201* on NM_004072.3) | Nonsense Mutation (SNP) | VAF 16/74 reads (22%) | catalogued as COSV56442308; called by muse, mutect2, varscan2
- CMYA5 | c.5468del p.K1823Rfs*17 | Frame Shift Del (DEL) | VAF 16/64 reads (25%) | catalogued as rs954878355; called by mutect2, pindel, varscan2
- CNR1 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.943); catalogued as rs140913272; called by muse, mutect2, varscan2
- CNTNAP5 | c.1654C>T p.P552S | Missense Mutation (SNP) | VAF 81/393 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs761628797, COSV70514576; called by muse, mutect2, varscan2
- COBL | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771936587, COSV54360071; called by muse, mutect2, varscan2
- COL12A1 | c.6253_6254insA p.L2085Hfs*4 | Frame Shift Ins (INS) | VAF 23/117 reads (20%) | catalogued as COSV59409429; called by mutect2, pindel, varscan2
- COL12A1 | c.5960G>A p.R1987H | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs201827443, COSV59409438; called by muse, mutect2, varscan2
- COL12A1 | c.3311G>A p.R1104Q | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.901); catalogued as COSV59409447; called by muse, mutect2, varscan2
- COL12A1 | c.628dup p.I210Nfs*4 | Frame Shift Ins (INS) | VAF 22/118 reads (19%) | catalogued as rs757069984; called by mutect2, varscan2
- COL15A1 | c.3476T>C p.L1159P | Missense Mutation (SNP) | VAF 57/248 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66649867; called by muse, mutect2, varscan2
- COL22A1 | c.2989C>A p.L997I | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.078); catalogued as COSV57363122; called by muse, mutect2, varscan2
- COL27A1 | c.284G>A p.G95D | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.96); catalogued as COSV61931211; called by muse, mutect2, varscan2
- COL3A1 | c.3011C>T p.A1004V | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.977); catalogued as COSV100483834; called by muse, mutect2
- COL5A1 | c.335G>A p.S112N | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV65675685; called by muse, mutect2, varscan2
- COL5A1 | c.1810G>A p.G604R | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65675695; called by muse, mutect2
- COL5A3 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as rs780192950, COSV53419871; called by muse, mutect2, varscan2
- COPA | c.2652_2654del p.E884del | In Frame Del (DEL) | VAF 50/216 reads (23%) | catalogued as rs778904236; called by pindel, varscan2
- CPAMD8 | c.5705C>T p.P1902L (on ENST00000651564; = p.P1855L on NM_015692.5) | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); catalogued as COSV50186810; called by muse, mutect2, varscan2
- CPNE2 | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 64/239 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs760327598, COSV51965228, COSV51965362; called by muse, mutect2, varscan2
- CPOX | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as rs200810233, COSV51639995; called by muse, mutect2, varscan2
- CR2 | c.2341C>T p.R781* | Nonsense Mutation (SNP) | VAF 15/158 reads (9%) | catalogued as rs766671758, COSV65506850; called by muse, mutect2, varscan2
- CRACD | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV51732740; called by muse, mutect2
- CREBBP | c.6596A>T p.Q2199L | Missense Mutation (SNP) | VAF 63/245 reads (26%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.039); catalogued as rs765821935, COSV52114705; called by muse, mutect2, varscan2
- CREBBP | c.5770G>A p.V1924M | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as rs368145743; ClinVar: not provided; called by muse, mutect2
- CRX | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749738655, CM157887, COSV55759760; called by muse, mutect2, varscan2
- CSF1R | c.92T>C p.V31A | Missense Mutation (SNP) | VAF 58/229 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); catalogued as COSV53844291; called by muse, mutect2, varscan2
- CSMD1 | c.6154G>A p.A2052T (on ENST00000520002; = p.A2051T on NM_033225.6) | Missense Mutation (SNP) | VAF 80/215 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs373726648; called by muse, mutect2, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 18/101 reads (18%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CSRNP2 | c.1020_1022del p.E340del | In Frame Del (DEL) | VAF 43/197 reads (22%) | catalogued as rs749407567; called by pindel, varscan2
- CTXN3 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 99/488 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs756665901, COSV65218951; called by muse, mutect2, varscan2
- CYP2A6 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 89/459 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs1355151029, COSV56537500; called by muse, mutect2, varscan2
- DAB1 | c.946G>A p.A316T (on ENST00000371231; = p.A283T on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as COSV100976712; called by muse, mutect2
- DAPP1 | c.622C>A p.L208I | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.608); catalogued as COSV56452947, COSV56453913; called by muse, varscan2
- DAXX | c.8C>T p.T3I | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as rs1321306896, COSV56473161; called by muse, mutect2, varscan2
- DCAF12L2 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 53/183 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs1374590191, COSV63580149; called by muse, mutect2, varscan2
- DCDC1 | c.670C>T p.L224F | Missense Mutation (SNP) | VAF 56/254 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.099); catalogued as COSV100662670, COSV60860499; called by muse, mutect2, varscan2
- DCLRE1A | c.1907del p.K636Rfs*31 | Frame Shift Del (DEL) | VAF 39/235 reads (17%) | catalogued as rs747223502; called by mutect2, pindel, varscan2
- DDX31 | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs200357088, COSV100140202, COSV60140101; called by muse, mutect2, varscan2
- DENND5B | c.320A>G p.E107G | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV60909003; called by muse, mutect2, varscan2
- DEPDC5 | c.3524C>T p.A1175V (on ENST00000400246; = p.A1244V on NM_014662.5) | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.049); catalogued as COSV56712031; called by muse, mutect2
- DERL2 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV50148031; called by muse, mutect2, varscan2
- DEUP1 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 39/214 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV53217304; called by muse, mutect2, varscan2
- DGCR2 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 47/198 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs144611145, COSV99593944; called by muse, mutect2, varscan2
- DGKQ | c.2470T>C p.S824P | Missense Mutation (SNP) | VAF 39/219 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53279428; called by muse, mutect2, varscan2
- DHX37 | c.911C>T p.T304M | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58139743; called by muse, mutect2
- DLC1 | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 73/223 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs377063736, COSV99365976; called by muse, mutect2, varscan2
- DLG1 | c.1954C>T p.R652* | Nonsense Mutation (SNP) | VAF 85/342 reads (25%) | catalogued as COSV58392366; called by muse, mutect2, varscan2
- DLGAP3 | c.254del p.G85Vfs*215 | Frame Shift Del (DEL) | VAF 29/146 reads (20%) | catalogued as rs762874947; called by mutect2, varscan2
- DLL4 | c.1457C>T p.S486L | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as rs779386236, COSV51073615; called by muse, mutect2, varscan2
- DMBT1 | c.88T>C p.Y30H | Missense Mutation (SNP) | VAF 21/392 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.511); catalogued as COSV57565093; called by muse, mutect2
- DMD | c.4119G>T p.Q1373H | Missense Mutation (SNP) | VAF 49/266 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV63796625; called by muse, mutect2, varscan2
- DNAH11 | c.12302G>A p.G4101D | Missense Mutation (SNP) | VAF 52/197 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs536274659, COSV60984773; called by muse, mutect2, varscan2
- DNAH2 | c.13094T>C p.F4365S | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66728190; called by muse, mutect2, varscan2
- DOC2A | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750445623, COSV58753020; called by muse, mutect2, varscan2
- DOCK2 | c.1361C>T p.A454V | Missense Mutation (SNP) | VAF 53/278 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs374175915; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 75/338 reads (22%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK6 | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1162772773, COSV52949801; called by muse, mutect2, varscan2
- DOCK8 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs771753565, COSV66635615; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DPP6 | c.1407G>T p.Q469H (on ENST00000377770 / NM_001364500.2; = p.Q407H on NM_001936.5) | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV59632065; called by muse, mutect2, varscan2
- DPP9 | c.1735G>A p.G579S (on ENST00000598800; = p.G608S on NM_139159.5) | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as rs755165617, COSV53594706; called by muse, mutect2, varscan2
- DPP9 | c.104G>A p.R35Q (on ENST00000598800; = p.R64Q on NM_139159.5) | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.426); catalogued as rs376189669; called by muse, mutect2, varscan2
- DPYSL2 | c.1537G>A p.V513I | Missense Mutation (SNP) | VAF 81/489 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.025); catalogued as rs1017213931, COSV60785466; called by muse, mutect2, varscan2
- DRD5 | c.1042G>A p.G348S | Missense Mutation (SNP) | VAF 51/193 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs755998605, COSV58578384; called by muse, mutect2, varscan2
- DSE | c.818T>C p.M273T | Missense Mutation (SNP) | VAF 47/262 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.051); catalogued as COSV59067776; called by muse, mutect2, varscan2
- DSG1 | c.2777T>C p.V926A | Missense Mutation (SNP) | VAF 66/326 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV57139805; called by muse, mutect2, varscan2
- DTNA | c.1672del p.A558Qfs*40 | Frame Shift Del (DEL) | VAF 78/336 reads (23%) | catalogued as COSV99314473; called by mutect2, pindel, varscan2
- DYNC1H1 | c.10357G>A p.V3453I | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.265); catalogued as rs778115137, COSV64143490; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYNC2H1 | c.3265G>C p.E1089Q | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.171); catalogued as COSV62108220; called by muse, mutect2, varscan2
- DYRK2 | c.498del p.K166Nfs*21 (on ENST00000344096 / NM_006482.3; = p.K93Nfs*21 on NM_003583.4) | Frame Shift Del (DEL) | VAF 9/48 reads (19%) | catalogued as COSV59846372; called by mutect2, pindel, varscan2
- ECE1 | c.1882C>T p.P628S | Missense Mutation (SNP) | VAF 30/284 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV51665340, COSV51669212; called by muse, mutect2
- EFCAB14 | c.647_648del p.V216Gfs*2 | Frame Shift Del (DEL) | VAF 64/330 reads (19%) | catalogued as rs780003341; called by pindel, varscan2
- EIF2A | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 79/370 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.335); catalogued as rs769029119, COSV56409111; called by muse, mutect2, varscan2
- EIF3A | c.2879G>A p.R960H | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as rs775041698, COSV64963692; called by muse, mutect2, varscan2
- ELAVL1 | c.59C>T p.T20M | Missense Mutation (SNP) | VAF 51/212 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV60966778; called by muse, mutect2, varscan2
- ELAVL4 | c.774-1G>T p.X258_splice | Splice Site (SNP) | VAF 69/257 reads (27%) | catalogued as COSV63919363; called by muse, mutect2, varscan2
- EML5 | c.5801C>T p.S1934L (on ENST00000380664; = p.S1942L on NM_183387.3) | Missense Mutation (SNP) | VAF 54/271 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764413285, COSV51774116; called by muse, mutect2, varscan2
- ENTHD1 | c.332A>G p.E111G | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57325659; called by muse, mutect2, varscan2
- ENTPD5 | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 34/120 reads (28%) | catalogued as rs748279577, COSV58224213; called by muse, mutect2, varscan2
- EPB41L2 | c.1267G>A p.V423M | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760954108, COSV61358804, COSV61359482; called by muse, mutect2, varscan2
- EPHX1 | c.183C>T p.H61= | Splice Region (SNP) | VAF 23/107 reads (21%) | catalogued as rs374642223, COSV55302364; called by muse, mutect2, varscan2
- EPN1 | c.1546G>A p.V516I (on ENST00000270460 / NM_001321263.1; = p.V490I on NM_013333.3) | Missense Mutation (SNP) | VAF 68/338 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs374261347; called by muse, varscan2
- EPS15L1 | c.2106C>T p.L702= | Splice Region (SNP) | VAF 15/129 reads (12%) | catalogued as rs780173380, COSV50168886; called by muse, mutect2, varscan2
- EQTN | c.77-3del | Splice Region (DEL) | VAF 31/136 reads (23%) | catalogued as rs768793415; called by mutect2, varscan2
- ERBIN | c.3830del p.P1277Lfs*14 (on ENST00000284037 / NM_001253697.2; = p.P1236Lfs*14 on NM_018695.4) | Frame Shift Del (DEL) | VAF 51/272 reads (19%) | catalogued as rs781559768; called by mutect2, pindel, varscan2
- ERICH3 | c.1852T>C p.S618P | Missense Mutation (SNP) | VAF 63/327 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.111); catalogued as COSV58619980; called by muse, mutect2, varscan2
- ERICH6 | c.161A>T p.E54V | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs753770853, COSV55798938; called by muse, mutect2
- ETV6 | c.1186A>G p.R396G | Missense Mutation (SNP) | VAF 64/249 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV56765377; called by muse, mutect2, varscan2
- EVI5 | c.648del p.F216Lfs*15 | Frame Shift Del (DEL) | VAF 38/210 reads (18%) | catalogued as rs1453325274; called by mutect2, pindel, varscan2
- FAM118B | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.909); catalogued as rs1188143414, COSV64157002; called by muse, mutect2, varscan2
- FAM120A | c.2576C>T p.P859L | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.214); catalogued as rs746136202, COSV52911865; called by muse, mutect2
- FAM122C | c.450C>G p.F150L (on ENST00000370784 / NM_001170779.3; = p.S149C on NM_138819.4) | Missense Mutation (SNP) | VAF 57/265 reads (22%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV100888263, COSV66196523; called by muse, mutect2, varscan2
- FAM171B | c.1864C>T p.R622* | Nonsense Mutation (SNP) | VAF 35/150 reads (23%) | catalogued as rs770515054, COSV100489062, COSV59000888; called by muse, mutect2, varscan2
- FANCD2OS | c.16C>A p.L6I | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV67560308; called by muse, mutect2, varscan2
- FANCE | c.929dup p.V311Sfs*2 | Frame Shift Ins (INS) | VAF 22/128 reads (17%) | catalogued as rs587778337; ClinVar: not provided; called by mutect2, varscan2
- FAR2 | c.529del p.I177Sfs*8 | Frame Shift Del (DEL) | VAF 27/137 reads (20%) | catalogued as rs757443519; called by mutect2, varscan2
- FASN | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60761878; called by muse, mutect2
- FAT1 | c.6193G>A p.V2065I | Missense Mutation (SNP) | VAF 47/209 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.096); catalogued as rs1165941519, COSV71676209; called by muse, mutect2, varscan2
- FAT4 | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 50/251 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV67901734; called by muse, mutect2, varscan2
- FAT4 | c.13497G>T p.E4499D | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.979); catalogued as COSV58711435; called by muse, mutect2, varscan2
- FBN3 | c.3666del p.C1223Afs*11 | Frame Shift Del (DEL) | VAF 23/115 reads (20%) | catalogued as COSV54474414; called by mutect2, pindel, varscan2
- FBN3 | c.2342G>A p.R781Q | Missense Mutation (SNP) | VAF 60/251 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs367947634; called by muse, mutect2, varscan2
- FBXL13 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs765103638, COSV57545194; called by muse, mutect2, varscan2
- FBXO3 | c.691C>T p.R231* | Nonsense Mutation (SNP) | VAF 76/346 reads (22%) | catalogued as COSV99682366; called by muse, varscan2
- FBXO30 | c.2068A>C p.N690H | Missense Mutation (SNP) | VAF 49/227 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.309); catalogued as rs781108999, COSV52791642, COSV52792596; called by muse, mutect2, varscan2
- FCGBP | c.8420G>A p.R2807Q | Missense Mutation (SNP) | VAF 297/3316 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0.019); catalogued as rs778200930; called by muse, mutect2
- FCRL1 | c.1087G>T p.G363W | Missense Mutation (SNP) | VAF 66/262 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.161); catalogued as COSV63824071; called by muse, mutect2, varscan2
- FGD3 | c.367del p.Q123Rfs*51 | Frame Shift Del (DEL) | VAF 38/151 reads (25%) | catalogued as rs777351004, COSV100490512; called by mutect2, pindel, varscan2
- FGR | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.009); catalogued as COSV64969860; called by muse, mutect2, varscan2
- FLG2 | c.4505G>T p.S1502I | Missense Mutation (SNP) | VAF 96/567 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as COSV66173987; called by muse, mutect2, varscan2
- FLNB | c.3801G>T p.K1267N | Missense Mutation (SNP) | VAF 66/267 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.666); catalogued as COSV55897698; called by muse, mutect2, varscan2
- FLNC | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 41/187 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs374847180; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOSL1 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 62/272 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs759636377, COSV100440990; called by muse, mutect2, varscan2
- FREM2 | c.1538C>T p.A513V | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV54854292; called by muse, mutect2, varscan2
- FRMD1 | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.443); catalogued as rs376385156; called by muse, mutect2, varscan2
- FRMPD4 | c.3313del p.S1105Vfs*3 | Frame Shift Del (DEL) | VAF 29/115 reads (25%) | catalogued as rs35659462; called by mutect2, pindel, varscan2
- FSTL4 | c.491_493del p.E164del | In Frame Del (DEL) | VAF 26/152 reads (17%) | catalogued as rs763836277; called by pindel, varscan2
- FSTL5 | c.826C>A p.L276M | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.876); catalogued as COSV60211506; called by muse, mutect2, varscan2
- FUBP1 | c.30del p.S11Lfs*43 | Frame Shift Del (DEL) | VAF 34/131 reads (26%) | catalogued as rs908264837; called by mutect2, pindel, varscan2
- FUT1 | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as rs1197384567, COSV59570272; called by muse, mutect2
- FZD10 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs770701893, COSV57472020; called by muse, mutect2, varscan2
- FZD8 | c.832G>A p.V278I | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.37); catalogued as COSV65968567; called by muse, mutect2, varscan2
- GAA | c.728A>G p.D243G | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV56412532; called by muse, mutect2, varscan2
- GABRA4 | c.87-1G>A p.X29_splice | Splice Site (SNP) | VAF 73/320 reads (23%) | catalogued as COSV99973839, COSV99974785; called by muse, mutect2, varscan2
- GABRA5 | c.269C>T p.T90M | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.954); catalogued as COSV59477279; called by muse, mutect2, varscan2
- GAD1 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.429); catalogued as rs868362629, COSV60154417; called by muse, mutect2, varscan2
- GALK2 | c.745C>A p.L249M | Missense Mutation (SNP) | VAF 14/264 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100508700, COSV59105433; called by muse, mutect2
- GALNT17 | c.383T>A p.I128N | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61194590; called by muse, mutect2, varscan2
- GALNT2 | c.580C>T p.R194* | Nonsense Mutation (SNP) | VAF 24/154 reads (16%) | catalogued as rs750040941, COSV64192875; called by muse, mutect2, varscan2
- GAS2L1 | c.1978G>A p.A660T | Missense Mutation (SNP) | VAF 70/311 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99329744; called by muse, mutect2, varscan2
- GCKR | c.1246C>T p.L416F | Missense Mutation (SNP) | VAF 84/315 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.519); catalogued as COSV53111207; called by muse, mutect2, varscan2
- GCN1 | c.3661C>T p.R1221* | Nonsense Mutation (SNP) | VAF 40/204 reads (20%) | catalogued as COSV100326128; called by muse, mutect2, varscan2
- GDF10 | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as rs782386699; called by muse, mutect2
- GLG1 | c.1674-1G>T p.X558_splice | Splice Site (SNP) | VAF 13/55 reads (24%) | catalogued as COSV52675260; called by muse, mutect2, varscan2
- GLI1 | c.821del p.G274Afs*6 | Frame Shift Del (DEL) | VAF 99/252 reads (39%) | catalogued as rs759448855, COSV99954330; called by mutect2, pindel, varscan2
- GLUD1 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 155/704 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); catalogued as rs749120493, COSV53281274; called by muse, mutect2, varscan2
- GLUD2 | c.387G>C p.W129C | Missense Mutation (SNP) | VAF 76/347 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV60153362; called by muse, mutect2, varscan2
- GNA11 | c.490G>A p.V164I | Missense Mutation (SNP) | VAF 64/276 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs775624350, COSV50027392; called by muse, mutect2, varscan2
- GNAZ | c.612dup p.Q205Afs*35 | Frame Shift Ins (INS) | VAF 16/94 reads (17%) | catalogued as rs752075537; called by mutect2, varscan2
- GNL1 | c.1085C>T p.T362I | Missense Mutation (SNP) | VAF 34/244 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs1185977601, COSV64835596; called by muse, mutect2, varscan2
- GOLGA7B | c.358C>A p.L120I | Missense Mutation (SNP) | VAF 47/212 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100086212; called by muse, mutect2, varscan2
- GPRASP1 | c.3053C>A p.P1018H | Missense Mutation (SNP) | VAF 55/260 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64356583; called by muse, mutect2, varscan2
- GPSM1 | c.1784C>T p.P595L | Missense Mutation (SNP) | VAF 109/324 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs782663989, COSV99396113; called by muse, mutect2, varscan2
- GREM1 | c.461T>C p.V154A | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1467505239, COSV55716522; called by muse, mutect2, varscan2
- GRIK1 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.185); catalogued as rs1216192211, COSV58733843; called by muse, mutect2, varscan2
- GRIK4 | c.2279G>A p.R760Q | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199658262, COSV101483617, COSV70802050; called by muse, mutect2, varscan2
- GRIK5 | c.1957G>T p.E653* | Nonsense Mutation (SNP) | VAF 20/144 reads (14%) | catalogued as COSV53486716; called by muse, mutect2, varscan2
- GRK5 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 62/262 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as rs146569660; called by muse, mutect2, varscan2
- GRM3 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV64478039; called by muse, varscan2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 30/125 reads (24%) | catalogued as rs754199513; called by mutect2, varscan2
- GUCY1B1 | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 46/305 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.197); catalogued as rs754640964, COSV52377571, COSV52379100; called by muse, mutect2, varscan2
- GXYLT1 | c.242G>T p.C81F | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.094); catalogued as COSV55143412; called by muse, mutect2, varscan2
- H1-6 | c.307A>G p.T103A | Missense Mutation (SNP) | VAF 97/427 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as COSV58091581; called by muse, mutect2, varscan2
- H2AC6 | c.133G>T p.G45W | Missense Mutation (SNP) | VAF 77/321 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58417711; called by muse, mutect2, varscan2
- HBS1L | c.1709G>A p.G570D | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750402350, COSV63202941; called by muse, mutect2, varscan2
- HEATR6 | c.698T>C p.M233T | Missense Mutation (SNP) | VAF 15/214 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV51749450; called by muse, mutect2
- HECW2 | c.2763del p.V922* | Frame Shift Del (DEL) | VAF 33/142 reads (23%) | catalogued as COSV99646682; called by mutect2, pindel, varscan2
- HEPACAM2 | c.887G>T p.G296V (on ENST00000394468 / NM_001039372.4; = p.G284V on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/316 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59063783; called by muse, mutect2, varscan2
- HERC2 | c.11378A>G p.N3793S | Missense Mutation (SNP) | VAF 60/311 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs1486170977, COSV55350009; called by muse, mutect2, varscan2
- HGFAC | c.1362dup p.R455Qfs*91 | Frame Shift Ins (INS) | VAF 32/160 reads (20%) | catalogued as rs761929917; called by mutect2, varscan2
- HIP1R | c.2835G>T p.R945S | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.014); catalogued as COSV53440016; called by muse, mutect2, varscan2
- HIPK2 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 107/408 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV61233312; called by muse, mutect2, varscan2
- HIPK3 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.018); catalogued as rs563248984, COSV57565200; called by muse, mutect2, varscan2
- HIRIP3 | c.1253G>A p.R418H | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs767923220, COSV54231903; called by muse, mutect2
- HKDC1 | c.2373C>T p.S791= | Splice Region (SNP) | VAF 23/132 reads (17%) | catalogued as rs754500258, COSV63579731; called by muse, mutect2, varscan2
- HLA-C | c.314T>G p.L105R | Missense Mutation (SNP) | VAF 34/658 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV66119501, COSV66119598; called by muse, mutect2
- HLA-E | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 65/271 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); catalogued as COSV64928022; called by muse, mutect2, varscan2
- HMGCS2 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 110/425 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1064797117, COSV65567142; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HNRNPL | c.1010del p.P337Hfs*58 | Frame Shift Del (DEL) | VAF 30/118 reads (25%) | catalogued as rs767148651; called by mutect2, varscan2
- HRC | c.1397del p.P466Qfs*12 | Frame Shift Del (DEL) | VAF 266/1217 reads (22%) | catalogued as COSV53255678; called by mutect2, pindel, varscan2
- HSPA2 | c.1864A>G p.S622G | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1566643513, COSV55968677; called by muse, mutect2, varscan2
- HTR1B | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 53/206 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64052011; called by muse, mutect2, varscan2
- HTR1D | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.15); catalogued as rs41268111, COSV58448220; called by muse, mutect2
- HTR1F | c.930del p.F310Lfs*2 | Frame Shift Del (DEL) | VAF 39/259 reads (15%) | catalogued as rs748579647; called by mutect2, varscan2
- HTR2B | c.943A>C p.T315P | Missense Mutation (SNP) | VAF 57/348 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV51450820; called by muse, mutect2, varscan2
- HUWE1 | c.3293C>T p.A1098V | Missense Mutation (SNP) | VAF 55/276 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV53344864; called by muse, mutect2, varscan2
- IDE | c.1706del p.L569Cfs*45 | Frame Shift Del (DEL) | VAF 16/76 reads (21%) | catalogued as rs771790236; called by mutect2, varscan2
- IFI6 | c.50C>T p.T17I | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.326); catalogued as COSV59270170; called by muse, mutect2, varscan2
- IFNL2 | c.314C>T p.T105M | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs200211932; called by muse, mutect2, varscan2
- IGF2R | c.3949del p.D1317Tfs*27 | Frame Shift Del (DEL) | VAF 32/140 reads (23%) | catalogued as rs760021495; called by mutect2, varscan2
- IGF2R | c.4303G>A p.V1435M | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.162); catalogued as rs1046637555, COSV63632236; called by muse, mutect2
- IGFBP4 | c.740T>G p.L247R | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV54098643; called by muse, mutect2
- IGHG2 | c.371del p.P124Qfs*8 | Frame Shift Del (DEL) | VAF 37/188 reads (20%) | catalogued as rs1567185953; called by mutect2, pindel, varscan2
- IGHMBP2 | c.2296G>A p.G766R | Missense Mutation (SNP) | VAF 52/188 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs201989968, COSV54823128; called by muse, mutect2, varscan2
- IGHV1-2 | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 36/590 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.06); catalogued as rs1061871; called by muse, mutect2
- IK | c.1115G>A p.R372Q | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.885); catalogued as rs746748598, COSV70258310; called by muse, mutect2, varscan2
- INPP4A | c.2264C>T p.A755V (on ENST00000074304 / NM_001134224.1; = p.A716V on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs749814576, COSV50841662; called by muse, mutect2, varscan2
- INPP5A | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.094); catalogued as rs576088004, COSV61253693; called by muse, mutect2, varscan2
- INPP5J | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.024); catalogued as rs1440144855, COSV58515619; called by muse, mutect2, varscan2
- INPP5J | c.2203A>G p.R735G (on ENST00000331075 / NM_001284285.2; = p.R367G on NM_001002837.2) | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as COSV53212991; called by muse, mutect2
- INSR | c.2516A>G p.Y839C | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV57174233; called by muse, mutect2, varscan2
- INTS12 | c.1000A>G p.T334A | Missense Mutation (SNP) | VAF 16/419 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.058); catalogued as COSV100415952; called by muse, mutect2
- INTS13 | c.1177C>T p.R393* | Nonsense Mutation (SNP) | VAF 13/60 reads (22%) | catalogued as rs761398033, COSV53905812; called by muse, mutect2, varscan2
- INTS3 | c.2699G>A p.S900N | Missense Mutation (SNP) | VAF 11/180 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99669874; called by muse, mutect2
- IP6K1 | c.752G>A p.S251N | Missense Mutation (SNP) | VAF 48/237 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57696842; called by muse, mutect2, varscan2
- IQCF2 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.18); catalogued as rs150954783; called by muse, mutect2, varscan2
- ITPKB | c.1886C>A p.P629H | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV55270751; called by muse, mutect2, varscan2
- ITPKC | c.1618T>C p.W540R | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as COSV54577698; called by muse, mutect2, varscan2
- IVD | c.1055A>G p.E352G (on ENST00000651168; = p.E349G on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.054); catalogued as COSV51102025; called by muse, mutect2, varscan2
- KANK1 | c.3508G>A p.V1170M | Missense Mutation (SNP) | VAF 53/225 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs150374219; called by muse, mutect2, varscan2
- KANK2 | c.1289del p.P430Rfs*5 | Frame Shift Del (DEL) | VAF 19/95 reads (20%) | catalogued as COSV62008356; called by mutect2, pindel, varscan2
- KAT6B | c.1430A>G p.H477R | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.062); catalogued as COSV54755574; called by muse, mutect2, varscan2
- KCNA6 | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 127/467 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV54974128, COSV99768741; called by muse, mutect2, varscan2
- KCNB2 | c.988C>T p.R330W | Missense Mutation (SNP) | VAF 98/277 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV73049336; called by muse, mutect2, varscan2
- KCNE4 | c.397del p.E133Rfs*3 | Frame Shift Del (DEL) | VAF 24/118 reads (20%) | catalogued as rs760505003; called by mutect2, pindel, varscan2
- KCNH4 | c.1736C>A p.P579Q | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52921449, COSV52921524; called by muse, mutect2, varscan2
- KCNH5 | c.1108A>G p.I370V | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.361); catalogued as rs1408916444, COSV59779915; called by muse, varscan2
- KCNK10 | c.854-1G>T p.X285_splice | Splice Site (SNP) | VAF 43/160 reads (27%) | catalogued as COSV56653388; called by muse, mutect2, varscan2
- KCNN1 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55842613; called by muse, mutect2, varscan2
- KIF13B | c.5119G>A p.V1707I | Missense Mutation (SNP) | VAF 41/233 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs1473922547, COSV68094814; called by muse, mutect2, varscan2
- KIF17 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 67/306 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs562792585, COSV56115839; called by muse, mutect2, varscan2
- KIFAP3 | c.607del p.C203Vfs*22 | Frame Shift Del (DEL) | VAF 22/127 reads (17%) | catalogued as rs1380692252; called by mutect2, pindel, varscan2
- KLC1 | c.1169G>T p.C390F | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55811715; called by mutect2, varscan2
- KLHL10 | c.194+2T>C p.X65_splice | Splice Site (SNP) | VAF 59/233 reads (25%) | catalogued as COSV53175269; called by muse, mutect2, varscan2
- KLHL31 | c.312del p.D105Tfs*15 | Frame Shift Del (DEL) | VAF 68/343 reads (20%) | catalogued as rs1227078726; called by mutect2, pindel, varscan2
- KLHL34 | c.861del p.R288Afs*7 | Frame Shift Del (DEL) | VAF 138/395 reads (35%) | catalogued as rs762518653; called by mutect2, pindel, varscan2
- KLHL42 | c.1194del p.C399Vfs*44 | Frame Shift Del (DEL) | VAF 10/93 reads (11%) | catalogued as rs749194179; called by mutect2, pindel, varscan2
- KLK13 | c.482G>A p.G161D | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50067669; called by muse, mutect2, varscan2
- KNDC1 | c.4010G>A p.R1337Q | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.752); catalogued as rs143908656; called by muse, mutect2, varscan2
- KPNB1 | c.2353+1G>A p.X785_splice | Splice Site (SNP) | VAF 30/124 reads (24%) | catalogued as COSV51600941; called by muse, mutect2, varscan2
- KRT17 | c.506T>C p.F169S | Missense Mutation (SNP) | VAF 155/677 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as COSV60862240; called by muse, mutect2, varscan2
- KRT23 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.869); catalogued as rs746484267, COSV52929182, COSV52929262; called by muse, mutect2
- KRT82 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 82/285 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs199503440; called by muse, mutect2, varscan2
- L1CAM | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 55/239 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.834); catalogued as rs1557092299, CM981152, COSV62829360; called by muse, mutect2, varscan2
- L3MBTL3 | c.1741G>A p.A581T | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as COSV62389161; called by muse, mutect2, varscan2
- LENG1 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 97/436 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs377766733, COSV55366816; called by muse, mutect2, varscan2
- LGR6 | c.2662C>T p.P888S (on ENST00000367278 / NM_001017403.1; = p.P836S on NM_021636.3) | Missense Mutation (SNP) | VAF 49/212 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV55167248; called by muse, mutect2, varscan2
- LILRB1 | c.680G>A p.R227H (on ENST00000427581; = p.R191H on NM_006669.6) | Missense Mutation (SNP) | VAF 83/441 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs543166769, COSV61121949; called by muse, mutect2, varscan2
- LIPG | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 64/269 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM092681, COSV54298577, COSV99724264; called by muse, mutect2, varscan2
- LLGL2 | c.817G>A p.V273M | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as rs754950482, COSV51417683; called by muse, mutect2, varscan2
- LMBRD1 | c.766C>T p.R256C (on ENST00000649011; = p.R234C on NM_018368.4) | Missense Mutation (SNP) | VAF 55/229 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs200207509, COSV65300305; called by muse, mutect2, varscan2
- LMF2 | c.965C>T p.A322V | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.053); catalogued as rs1460384029, COSV53319385; called by muse, mutect2, varscan2
- LNX2 | c.11_13del p.T4del | In Frame Del (DEL) | VAF 62/286 reads (22%) | catalogued as rs775763450; called by pindel, varscan2
- LONRF1 | c.1885G>A p.V629M | Missense Mutation (SNP) | VAF 56/177 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1029429189, COSV68037790; called by muse, mutect2, varscan2
- LRFN2 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.389); catalogued as rs751353594, COSV57835290; called by muse, mutect2, varscan2
- LRIG3 | c.2494C>A p.H832N | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100292359, COSV57870673; called by muse, mutect2, varscan2
- LRRK1 | c.5358G>A p.M1786I | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV52627498; called by muse, mutect2, varscan2
- MAGEA12 | c.207del p.T70Pfs*38 | Frame Shift Del (DEL) | VAF 113/568 reads (20%) | catalogued as COSV63294998; called by mutect2, pindel, varscan2
- MAGEE1 | c.1663G>A p.A555T | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.028); catalogued as COSV63912328; called by muse, mutect2, varscan2
- MAGEL2 | c.3068G>T p.R1023M | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV58566670, COSV58569379; called by muse, mutect2, varscan2
- MAMDC4 | c.1829G>A p.R610H | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs766484735, COSV58071690, COSV58073430; called by muse, mutect2, varscan2
- MAP3K5 | c.875T>C p.L292S | Missense Mutation (SNP) | VAF 50/226 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62892562; called by muse, mutect2, varscan2
- MAP7D1 | c.1492del p.R498Efs*77 | Frame Shift Del (DEL) | VAF 31/138 reads (22%) | catalogued as COSV100294600; called by mutect2, pindel, varscan2
- MAP9 | c.1700del p.K567Rfs*13 | Frame Shift Del (DEL) | VAF 22/125 reads (18%) | catalogued as rs1215313075; called by mutect2, pindel, varscan2
- MARCKSL1 | c.310T>C p.S104P | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.518); catalogued as COSV61481921; called by muse, mutect2, varscan2
- MARVELD2 | c.614C>G p.A205G | Missense Mutation (SNP) | VAF 141/814 reads (17%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.572); catalogued as COSV57782569; called by muse, mutect2, varscan2
- MAST3 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 20/382 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV99446442; called by muse, mutect2
- MCF2L2 | c.580G>A p.G194S | Missense Mutation (SNP) | VAF 50/269 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs995431665, COSV61054957; called by muse, mutect2, varscan2
- MCM2 | c.112C>A p.L38I | Missense Mutation (SNP) | VAF 48/209 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV54037779; called by muse, mutect2, varscan2
- MED12L | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 41/539 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs776507674, COSV99854972; called by muse, mutect2
- MED16 | c.736G>A p.V246M | Missense Mutation (SNP) | VAF 46/188 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV54132317; called by muse, mutect2, varscan2
- MEX3B | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV61663365; called by muse, mutect2, varscan2
- MFSD5 | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 68/255 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as rs147930954; called by muse, mutect2, varscan2
- MIA2 | c.1089dup p.D364Rfs*5 | Frame Shift Ins (INS) | VAF 24/94 reads (26%) | catalogued as rs538500709; called by mutect2, varscan2
- MICAL1 | c.1488C>A p.D496E | Missense Mutation (SNP) | VAF 35/218 reads (16%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.527); catalogued as COSV62196597; called by muse, mutect2, varscan2
- MICAL2 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1396469560, COSV56327169; called by muse, mutect2, varscan2
- MIER3 | c.1027del p.R343Dfs*15 (on ENST00000381199 / NM_001297599.2; = p.R342Dfs*15 on NM_152622.4) | Frame Shift Del (DEL) | VAF 47/232 reads (20%) | catalogued as COSV67083276; called by mutect2, pindel, varscan2
- MITF | c.526G>A p.A176T (on ENST00000448226 / NM_006722.3; = p.A70T on NM_000248.4) | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.879); catalogued as rs760770591, COSV58831516; called by muse, mutect2, varscan2
- MLH3 | c.1358T>C p.M453T | Missense Mutation (SNP) | VAF 64/300 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV53136082; called by muse, mutect2, varscan2
- MLST8 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 56/206 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1386926752, COSV57031493; called by muse, mutect2, varscan2
- MNX1 | c.1098C>A p.D366E | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV53319719; called by muse, mutect2
- MOCOS | c.2327G>A p.R776H | Missense Mutation (SNP) | VAF 39/255 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776357546, COSV54341525; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MPDZ | c.5459G>T p.S1820I (on ENST00000319217 / NM_001330637.2; = p.S1787I on NM_001261406.2 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV100057759; called by muse, mutect2, varscan2
- MPPE1 | c.917G>A p.S306N | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.102); catalogued as rs536672004, COSV52334833; called by muse, mutect2, varscan2
- MRPL16 | c.673G>A p.G225S | Missense Mutation (SNP) | VAF 69/280 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55701757; called by muse, mutect2, varscan2
- MRPL16 | c.592A>G p.M198V | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV55701762; called by muse, mutect2, varscan2
- MRPL2 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1219001742, COSV54822602; called by muse, mutect2, varscan2
- MRPL24 | c.52dup p.H18Pfs*34 | Frame Shift Ins (INS) | VAF 10/65 reads (15%) | catalogued as rs760797871; called by mutect2, varscan2
- MSH4 | c.1993A>G p.N665D | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV99592696; called by muse, mutect2
- MSRA | c.705del p.K235Nfs*14 | Frame Shift Del (DEL) | VAF 37/108 reads (34%) | catalogued as rs758604537, COSV57799292; called by pindel, varscan2
- MTG1 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 44/190 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.489); catalogued as rs372230583; called by muse, mutect2, varscan2
- MTOR | c.4439G>A p.R1480H | Missense Mutation (SNP) | VAF 61/223 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs780930764, COSV63868373; called by muse, mutect2, varscan2
- MTREX | c.1634C>T p.P545L | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV57930634; called by muse, mutect2, varscan2
- MTUS1 | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.167); catalogued as COSV50599143; called by muse, mutect2, varscan2
- MUC16 | c.2222G>A p.S741N | Missense Mutation (SNP) | VAF 77/363 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.096); catalogued as COSV67497542; called by muse, mutect2, varscan2
- MUC5B | c.1011G>T p.E337D | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV71595926; called by muse, mutect2
- MUC5B | c.3101T>C p.I1034T | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV71595928; called by muse, mutect2, varscan2
- MYBBP1A | c.2180A>G p.E727G | Missense Mutation (SNP) | VAF 55/288 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.318); catalogued as rs755542622, COSV54597197; called by muse, mutect2, varscan2
- MYD88 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57181233; called by muse, mutect2, varscan2
- MYH2 | c.1084T>C p.Y362H | Missense Mutation (SNP) | VAF 109/445 reads (24%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV55449865; called by muse, mutect2, varscan2
- MYH9 | c.272G>A p.C91Y | Missense Mutation (SNP) | VAF 98/390 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV53394072; called by muse, mutect2, varscan2
- MYLK2 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.062); catalogued as COSV65660079; called by muse, mutect2, varscan2
- MYOD1 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV51455935; called by muse, mutect2, varscan2
- MYOM2 | c.56C>A p.S19Y | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50785457; called by muse, mutect2, varscan2
- MYOM2 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 27/297 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV50761673; called by muse, mutect2
- NAE1 | c.158-1G>T p.X53_splice | Splice Site (SNP) | VAF 39/142 reads (27%) | catalogued as rs746007943, COSV51978645; called by muse, mutect2, varscan2
- NAIF1 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.679); catalogued as COSV66090893; called by muse, mutect2, varscan2
- NAV2 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs754250510, COSV62336923; called by muse, mutect2, varscan2
- NCAPG | c.1118+2T>C p.X373_splice | Splice Site (SNP) | VAF 19/76 reads (25%) | catalogued as COSV52273023; called by muse, mutect2, varscan2
- NCAPH2 | c.685G>A p.V229M | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.537); catalogued as rs574318930, COSV53219197; called by muse, mutect2, varscan2
- NCKAP5 | c.1573A>G p.T525A | Missense Mutation (SNP) | VAF 68/235 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.121); catalogued as COSV58478144; called by muse, mutect2, varscan2
- NCOA2 | c.2847G>A p.M949I | Missense Mutation (SNP) | VAF 57/288 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV51223727; called by muse, mutect2, varscan2
- NDUFA10 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 83/379 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as rs558134843, COSV53153406; called by muse, mutect2, varscan2
- NDUFV1 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 69/255 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs755312472, COSV59596847; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- NEDD4L | c.941G>T p.R314M | Missense Mutation (SNP) | VAF 11/194 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV99893491, COSV99896800; called by muse, mutect2
- NEDD4L | c.1091G>A p.R364H (on ENST00000400345 / NM_001144967.3; = p.R243H on NM_001144964.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.55); catalogued as rs373080858; called by muse, mutect2, varscan2
- NEK1 | c.2270G>A p.R757H | Missense Mutation (SNP) | VAF 58/374 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757319297, COSV71455754; called by muse, mutect2, varscan2
- NEK11 | c.1620A>G p.L540= | Splice Region (SNP) | VAF 46/195 reads (24%) | catalogued as COSV67286400; called by muse, mutect2, varscan2
- NF2 | c.1075A>T p.R359W | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58531637; called by muse, mutect2, varscan2
- NLRP2 | c.1868C>T p.A623V | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.16); catalogued as COSV54761067; called by muse, mutect2, varscan2
- NLRP5 | c.1471G>A p.V491I | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs368451354; called by muse, varscan2
- NOC4L | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs375092329; called by muse, mutect2, varscan2
- NPAP1 | c.31G>T p.G11W | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.75); catalogued as COSV61507825, COSV61511976; called by muse, mutect2, varscan2
- NPTX2 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.295); catalogued as rs757073029, COSV55719626; called by muse, mutect2, varscan2
- NPY4R | c.134T>C p.V45A | Missense Mutation (SNP) | VAF 58/393 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.024); catalogued as COSV65399411; called by muse, mutect2, varscan2
- NR2E1 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 14/313 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as COSV100934643; called by muse, mutect2
- NRBF2 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs745822881, COSV53260721; called by muse, mutect2, varscan2
- NRK | c.3080G>T p.S1027I | Missense Mutation (SNP) | VAF 85/347 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs1474725336, COSV54608031; called by muse, mutect2, varscan2
- NUP210 | c.1483G>A p.A495T | Missense Mutation (SNP) | VAF 58/219 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV54414889; called by muse, mutect2, varscan2
- OBSCN | c.10658C>T p.A3553V | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as COSV52835927; called by muse, mutect2, varscan2
- OCA2 | c.1349C>T p.T450M | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772019064, CM085601, CM100992, COSV62337789, COSV62353533; called by muse, mutect2, varscan2
- ODF1 | c.350C>A p.A117D | Missense Mutation (SNP) | VAF 41/208 reads (20%) | SIFT tolerated, low confidence (0.38); PolyPhen possibly damaging (0.734); catalogued as COSV53434377; called by muse, mutect2, varscan2
- OPCML | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 66/314 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs760528510, COSV59453436; called by muse, mutect2, varscan2
- OPLAH | c.1158G>A p.G386= | Splice Region (SNP) | VAF 19/402 reads (5%) | catalogued as COSV101470934, COSV101470968; called by muse, mutect2
- OPRPN | c.390dup p.L131Sfs*9 | Frame Shift Ins (INS) | VAF 50/336 reads (15%) | catalogued as rs1560534905; called by mutect2, varscan2
- OPTN | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV53813645; called by muse, mutect2, varscan2
- OR1D5 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 59/633 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1224228789, COSV73859562; called by muse, mutect2
- OR2L3 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 64/285 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV63456475; called by muse, mutect2, varscan2
- OR4K2 | c.404T>G p.V135G | Missense Mutation (SNP) | VAF 76/874 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV100064810; called by muse, mutect2
- OR51B2 | c.619C>A p.L207I | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.77); catalogued as COSV60918015; called by muse, mutect2, varscan2
- OR5K2 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 40/251 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV71143548; called by muse, mutect2, varscan2
- OS9 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57784830, COSV99232899; called by muse, mutect2, varscan2
- OSBPL2 | c.662T>C p.L221P (on ENST00000313733 / NM_144498.4; = p.L209P on NM_014835.4) | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV58220299; called by muse, mutect2, varscan2
- OTOP2 | c.1651G>T p.A551S | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.254); catalogued as rs767473175, COSV58883944; called by muse, mutect2, varscan2
- OXSR1 | c.512dup p.L171Ffs*6 | Frame Shift Ins (INS) | VAF 57/323 reads (18%) | catalogued as rs1559518427; called by mutect2, pindel, varscan2
- P3H3 | c.1714G>T p.E572* | Nonsense Mutation (SNP) | VAF 30/149 reads (20%) | catalogued as COSV99301770; called by muse, mutect2, varscan2
- PALLD | c.1426C>T p.R476W | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs535947672, COSV54974843, COSV54996218; called by muse, mutect2, varscan2
- PARVB | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV58692058; called by muse, mutect2, varscan2
- PATZ1 | c.883G>T p.G295C | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53231477; called by muse, mutect2, varscan2
- PAX5 | c.928A>G p.T310A | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.31); catalogued as rs982157908, COSV63913978; called by muse, mutect2, varscan2
- PAX8 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.63); catalogued as rs1280163912, COSV54512372; called by muse, mutect2, varscan2
- PAXBP1 | c.2098T>C p.S700P | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51612696; called by muse, varscan2
- PCDH9 | c.3141G>A p.S1047= (on ENST00000377865 / NM_203487.3; = p.S1013= on NM_020403.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 19/69 reads (28%) | catalogued as rs776019485, COSV60594482; called by muse, mutect2, varscan2
- PCDHA11 | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 136/588 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.035); catalogued as COSV56542290; called by muse, mutect2, varscan2
- PCDHA11 | c.2188G>A p.A730T | Missense Mutation (SNP) | VAF 17/416 reads (4%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.006); catalogued as COSV56494142; called by muse, mutect2
- PCDHA4 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.926); catalogued as rs267600385, COSV63540193; called by muse, mutect2
- PCDHB6 | c.1585G>A p.V529M | Missense Mutation (SNP) | VAF 81/364 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50730777; called by muse, mutect2, varscan2
- PCDHB7 | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.453); catalogued as rs1554280024, COSV50770160; called by muse, mutect2, varscan2
- PCLO | c.7325del p.K2442Sfs*2 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | catalogued as COSV61618667; called by mutect2, varscan2
- PDE1B | c.1565del p.P522Hfs*25 | Frame Shift Del (DEL) | VAF 16/96 reads (17%) | catalogued as rs780236743; called by mutect2, pindel, varscan2
- PDZD2 | c.2099G>A p.G700E | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.144); catalogued as COSV56874309; called by muse, mutect2, varscan2
- PDZRN3 | c.2569A>G p.S857G | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV55216873; called by muse, mutect2, varscan2
- PDZRN4 | c.2534C>T p.A845V (on ENST00000402685 / NM_001164595.2; = p.A587V on NM_013377.4) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV54218735; called by muse, mutect2
- PHACTR2 | c.587dup p.N196Kfs*7 | Frame Shift Ins (INS) | VAF 22/94 reads (23%) | catalogued as rs756307843; called by mutect2, varscan2
- PHF23 | c.726del p.S243Vfs*24 | Frame Shift Del (DEL) | VAF 27/114 reads (24%) | catalogued as COSV50036587; called by mutect2, pindel, varscan2
- PHKB | c.1802C>T p.A601V | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.23); catalogued as rs192099645, COSV54515704; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PHLDA2 | c.137G>C p.R46P | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV56540820; called by muse, mutect2, varscan2
- PHTF1 | c.1637dup p.M547Hfs*10 | Frame Shift Ins (INS) | VAF 105/478 reads (22%) | catalogued as rs750248180; called by mutect2, varscan2
- PIK3C3 | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.686); catalogued as rs200002230, COSV56285287; called by muse, mutect2, varscan2
- PKMYT1 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as rs761362077, COSV51893007; called by muse, mutect2, varscan2
- PKP2 | c.1555A>G p.M519V | Missense Mutation (SNP) | VAF 63/203 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs751517092, COSV50751319; called by muse, mutect2, varscan2
- PLD2 | c.2609G>A p.R870H | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs201356383, COSV54010419; called by muse, mutect2, varscan2
- PLEKHM1 | c.3125G>A p.R1042H | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs759260422, COSV51818599; called by muse, mutect2, varscan2
- PLIN3 | c.932G>A p.G311D | Missense Mutation (SNP) | VAF 48/199 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.055); catalogued as rs574992524, COSV55737384; called by muse, mutect2, varscan2
- PLOD1 | c.1786G>A p.V596M | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs149654030; called by muse, mutect2, varscan2
- PLPP2 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.261); catalogued as rs753966441, COSV54120495; called by muse, mutect2
- PLXNA3 | c.49del p.A17Pfs*12 | Frame Shift Del (DEL) | VAF 52/178 reads (29%) | catalogued as rs782247826; called by mutect2, varscan2
- PLXNB3 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377546863, COSV62802887; called by muse, mutect2, varscan2
- PLXNB3 | c.4993G>A p.E1665K | Missense Mutation (SNP) | VAF 47/192 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372327696, COSV62798626; called by muse, mutect2, varscan2
- PNLDC1 | c.1124+2T>C p.X375_splice | Splice Site (SNP) | VAF 107/496 reads (22%) | catalogued as COSV51708463; called by muse, mutect2, varscan2
- PNPLA5 | c.551T>C p.I184T | Missense Mutation (SNP) | VAF 45/205 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV53376482; called by muse, mutect2, varscan2
- PPIB | c.205_206del p.V69Sfs*6 | Frame Shift Del (DEL) | VAF 33/180 reads (18%) | catalogued as rs771118063; called by mutect2, pindel, varscan2
- PPIL6 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.511); catalogued as rs763721663, COSV70021581; called by muse, varscan2
- PPP1R10 | c.930del p.V311Yfs*79 | Frame Shift Del (DEL) | VAF 28/100 reads (28%) | catalogued as rs746108087; called by mutect2, varscan2
- PPP1R18 | c.287A>G p.Q96R | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs775362882, COSV51299553; called by muse, mutect2, varscan2
- PPP1R1C | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 65/277 reads (23%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs768049964, COSV54714751; called by muse, mutect2, varscan2
- PRAG1 | c.2423G>C p.G808A | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.3); catalogued as COSV58167583; called by muse, varscan2
- PRKAG2 | c.202G>A p.G68S | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs730880970, COSV55242886; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- PRLHR | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 56/180 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.041); catalogued as rs1328613305, COSV53302763; called by muse, mutect2, varscan2
- PROSER1 | c.1339A>G p.T447A | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV100613090; called by muse, mutect2, varscan2
- PRPF38B | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs1158752325, COSV100898349; called by muse, mutect2
- PSKH2 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs146849251; called by muse, mutect2, varscan2
- PSPC1 | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 83/897 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as rs770352525, COSV100142737; called by muse, mutect2
- PTCH2 | c.3220C>T p.L1074F | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.993); catalogued as rs1374831734, COSV63400405; called by muse, mutect2, varscan2
- PTCHD3 | c.2057dup p.N686Kfs*6 | Frame Shift Ins (INS) | VAF 28/109 reads (26%) | catalogued as rs750923568; called by mutect2, varscan2
- PTGER3 | c.22G>A p.G8R | Missense Mutation (SNP) | VAF 94/457 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV60698541; called by muse, mutect2, varscan2
- PTPDC1 | c.778G>A p.A260T (on ENST00000375360 / NM_177995.3; = p.A312T on NM_152422.4) | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.174); catalogued as rs896298362, COSV56626849, COSV99997776; called by muse, mutect2, varscan2
- PTPRB | c.4633A>G p.N1545D | Missense Mutation (SNP) | VAF 116/454 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV54255247; called by muse, mutect2, varscan2
- PTPRO | c.3418G>A p.V1140M (on ENST00000281171 / NM_030667.3; = p.V1112M on NM_002848.4) | Missense Mutation (SNP) | VAF 53/209 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55524088; called by muse, mutect2, varscan2
- PURG | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 46/395 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53299779; called by muse, mutect2, varscan2
- PYGO1 | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV57350468; called by muse, mutect2, varscan2
- QRICH2 | c.86A>C p.E29A | Missense Mutation (SNP) | VAF 47/220 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV53158356; called by muse, mutect2, varscan2
- RAB40C | c.751G>A p.G251S | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs145997805; called by muse, mutect2, varscan2
- RAD17 | c.1112G>A p.R371Q (on ENST00000380774 / NM_133339.2; = p.R360Q on NM_002873.1) | Missense Mutation (SNP) | VAF 28/328 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs759753593, COSV51457167; called by muse, mutect2
- RADIL | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 55/258 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1289457128, COSV68203952; called by muse, mutect2, varscan2
- RALGAPA1 | c.587del p.P196Hfs*20 | Frame Shift Del (DEL) | VAF 49/253 reads (19%) | catalogued as COSV99353059; called by mutect2, pindel, varscan2
- RANBP2 | c.1594T>C p.W532R | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99313488; called by muse, mutect2, varscan2
- RANBP6 | c.1753G>A p.A585T | Missense Mutation (SNP) | VAF 50/207 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV52391789, COSV99424375; called by muse, mutect2, varscan2
- RAPGEF1 | c.3217C>T p.R1073W | Missense Mutation (SNP) | VAF 142/627 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs747478083, COSV64702635; called by muse, mutect2, varscan2
- RAPGEF1 | c.2866G>A p.E956K | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1266562115, COSV64699509; called by muse, mutect2
- RAPH1 | c.2294del p.P765Hfs*19 | Frame Shift Del (DEL) | VAF 53/104 reads (51%) | catalogued as rs760908242; called by mutect2, varscan2
- RASAL1 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.083); catalogued as COSV55660184, COSV99922088; called by muse, mutect2, varscan2
- RBM19 | c.2570A>G p.E857G | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1313786859, COSV55699109; called by muse, mutect2, varscan2
- RBM6 | c.1558-1G>A p.X520_splice | Splice Site (SNP) | VAF 78/287 reads (27%) | catalogued as COSV56488682; called by muse, mutect2, varscan2
- RFX7 | c.2754dup p.S919Qfs*4 (on ENST00000559447 / NM_001368074.1; = p.S1016Qfs*4 on NM_022841.7 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 47/224 reads (21%) | catalogued as rs753737369; called by mutect2, varscan2
- RGS19 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 62/239 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.907); catalogued as rs762327545, COSV58659601; called by muse, mutect2, varscan2
- RHCG | c.100T>G p.F34V | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV51518692; called by muse, mutect2, varscan2
- RIMBP2 | c.1327A>C p.N443H | Missense Mutation (SNP) | VAF 99/386 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV55485435; called by muse, mutect2, varscan2
- RIMBP2 | c.847G>A p.G283R | Missense Mutation (SNP) | VAF 125/466 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs375328741; called by muse, mutect2, varscan2
- RIMS1 | c.54del p.M19Cfs*7 | Frame Shift Del (DEL) | VAF 32/172 reads (19%) | catalogued as rs1378143186; called by pindel, varscan2
- RMC1 | c.112G>A p.V38I | Missense Mutation (SNP) | VAF 166/574 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); catalogued as COSV52575035; called by muse, varscan2
- RNF112 | c.1343C>T p.P448L | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as rs759270591, COSV71327128; called by muse, varscan2
- RNF125 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 93/400 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.05); catalogued as rs1399200886, COSV54187076; called by muse, mutect2, varscan2
- RNF126 | c.166G>T p.A56S | Missense Mutation (SNP) | VAF 60/258 reads (23%) | SIFT tolerated (0.94); PolyPhen benign (0.041); catalogued as COSV52779735; called by muse, varscan2
- RNF148 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 79/359 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs377391654, COSV57350295; called by muse, mutect2, varscan2
- RNF20 | c.2019+2T>C p.X673_splice | Splice Site (SNP) | VAF 41/130 reads (32%) | catalogued as COSV66662523; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 67/196 reads (34%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- ROR1 | c.2126A>C p.Q709P | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64293802; called by muse, mutect2, varscan2
- RPL10L | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as rs1180090060, COSV53559908, COSV53560536; called by muse, mutect2, varscan2
- RPL5 | c.619T>C p.Y207H | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.35); catalogued as rs746120360, COSV59873196; called by muse, mutect2, varscan2
- RPTOR | c.1802A>G p.H601R | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as COSV60819499; called by muse, mutect2, varscan2
- RTL3 | c.983G>A p.C328Y | Missense Mutation (SNP) | VAF 72/275 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1206024217, COSV58186108; called by muse, mutect2, varscan2
- S100A9 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 52/167 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV64199768; called by muse, mutect2, varscan2
- SALL4 | c.2443A>G p.S815G | Missense Mutation (SNP) | VAF 90/405 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV53856584; called by muse, mutect2, varscan2
- SASH1 | c.2881C>T p.H961Y | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV66566509; called by muse, mutect2, varscan2
- SCUBE3 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs754858014, COSV51458203, COSV51460890; called by muse, mutect2, varscan2
- SEMA3D | c.2182G>A p.D728N | Missense Mutation (SNP) | VAF 130/605 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.75); catalogued as rs1047048299, COSV52394259, COSV99033645; called by muse, mutect2, varscan2
- SEMA5B | c.3020G>A p.R1007H | Missense Mutation (SNP) | VAF 37/196 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs916876645, COSV52093569; called by muse, mutect2, varscan2
- SEMA6C | c.38T>G p.L13R | Missense Mutation (SNP) | VAF 105/548 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59008199; called by muse, mutect2, varscan2
- SEPTIN11 | c.398T>C p.L133S | Missense Mutation (SNP) | VAF 44/222 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV99346696; called by muse, varscan2
- SERPINE3 | c.658C>A p.L220I | Missense Mutation (SNP) | VAF 59/307 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.158); catalogued as COSV68545147; called by muse, mutect2, varscan2
- SFSWAP | c.2048G>A p.R683H | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1035678431, COSV55523488; called by muse, mutect2
- SGIP1 | c.100C>A p.Q34K | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.011); catalogued as COSV52779957; called by muse, mutect2, varscan2
- SGIP1 | c.1960A>G p.T654A | Missense Mutation (SNP) | VAF 44/246 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV52779964; called by muse, mutect2, varscan2
- SGO2 | c.1929del p.G644Vfs*18 | Frame Shift Del (DEL) | VAF 75/302 reads (25%) | catalogued as rs1260834379; called by mutect2, pindel, varscan2
- SH3TC2 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); catalogued as COSV60460765, COSV60468337; called by muse, mutect2, varscan2
- SIDT2 | c.1754T>C p.M585T | Missense Mutation (SNP) | VAF 57/308 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); catalogued as rs766311715, COSV54061343; called by muse, mutect2, varscan2
- SIPA1L1 | c.436T>C p.S146P | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.102); catalogued as COSV62174177; called by muse, mutect2, varscan2
- SLC12A7 | c.908del p.P303Rfs*129 | Frame Shift Del (DEL) | VAF 50/237 reads (21%) | catalogued as COSV53758976; called by mutect2, pindel, varscan2
- SLC13A4 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.458); catalogued as COSV62462962; called by muse, mutect2
- SLC15A2 | c.1002+2T>C p.X334_splice | Splice Site (SNP) | VAF 39/213 reads (18%) | catalogued as COSV55201311; called by muse, mutect2, varscan2
- SLC1A4 | c.1375A>G p.T459A | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.439); catalogued as rs1331776259, COSV52236189; called by muse, mutect2, varscan2
- SLC22A10 | c.1395G>T p.R465S | Missense Mutation (SNP) | VAF 43/213 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as COSV60423781; called by muse, mutect2, varscan2
- SLC22A16 | c.824C>A p.S275Y | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57932937, COSV57935262; called by muse, mutect2, varscan2
- SLC22A3 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142228053; called by muse, mutect2, varscan2
- SLC2A4 | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs770842692, COSV50302746, COSV99142732; called by muse, mutect2, varscan2
- SLC36A3 | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as rs142309332; called by muse, mutect2, varscan2
- SLC45A4 | c.765G>T p.E255D (on ENST00000517878 / NM_001286646.2; = p.E204D on NM_001080431.2) | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50148515, COSV50196241; called by muse, mutect2, varscan2
- SLC5A1 | c.892G>A p.V298M | Missense Mutation (SNP) | VAF 69/255 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56689271; called by muse, mutect2, varscan2
- SLC5A2 | c.1952G>A p.R651H | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs368071047; called by muse, mutect2, varscan2
- SLC6A17 | c.1630G>A p.A544T | Missense Mutation (SNP) | VAF 59/246 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV58991750; called by muse, mutect2, varscan2
- SLC7A10 | c.471del p.T158Pfs*12 | Frame Shift Del (DEL) | VAF 44/236 reads (19%) | catalogued as rs753589038, COSV53507811; called by mutect2, pindel, varscan2
- SLC8A2 | c.658del p.S220Pfs*12 | Frame Shift Del (DEL) | VAF 18/98 reads (18%) | catalogued as rs748349403; called by mutect2, pindel, varscan2
- SLCO1C1 | c.1892G>T p.R631I | Missense Mutation (SNP) | VAF 54/268 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56881011; called by muse, mutect2, varscan2
- SLIT3 | c.1510G>A p.V504M | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.21); catalogued as rs73802391, COSV60627380; called by muse, mutect2
- SMARCD2 | c.1480C>T p.R494* | Nonsense Mutation (SNP) | VAF 24/82 reads (29%) | catalogued as COSV56742389; called by muse, mutect2, varscan2
- SND1 | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 91/386 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1013201053, COSV61250097; called by muse, mutect2, varscan2
- SNX18 | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 14/273 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV57993558; called by muse, mutect2
- SNX18 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs141392594; called by muse, mutect2
- SNX18 | c.1188G>T p.K396N | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as COSV57992690; called by muse, mutect2, varscan2
- SOD2 | c.407C>T p.T136M | Missense Mutation (SNP) | VAF 31/190 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.47); catalogued as rs372074075; called by muse, mutect2, varscan2
- SOGA3 | c.1217G>A p.C406Y | Missense Mutation (SNP) | VAF 57/255 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64109009; called by muse, mutect2, varscan2
- SORCS2 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 15/370 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs892685664; called by muse, mutect2
- SPAG17 | c.4726A>G p.T1576A | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1423258634, COSV100310813, COSV60461836; called by muse, mutect2
- SPANXN3 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 65/315 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as COSV65140874; called by muse, mutect2, varscan2
- SPATA6L | c.1102T>C p.S368P (on ENST00000461761 / NM_001353484.2; = p.S310P on NM_001039395.4 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as COSV67891305; called by muse, mutect2, varscan2
- SPINT1 | c.958del p.Q320Rfs*133 | Frame Shift Del (DEL) | VAF 66/272 reads (24%) | catalogued as COSV100688873; called by mutect2, pindel, varscan2
- SPOUT1 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs746723809, COSV63509144; called by muse, mutect2, varscan2
- SPTB | c.4028A>G p.K1343R | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.771); catalogued as COSV67635435, COSV67635564; called by muse, mutect2, varscan2
- SPTLC1 | c.781-2A>G p.X261_splice | Splice Site (SNP) | VAF 15/79 reads (19%) | catalogued as COSV52767481; called by muse, mutect2, varscan2
- SRBD1 | c.1733C>T p.A578V | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.212); catalogued as rs61746112; called by muse, mutect2, varscan2
- SRFBP1 | c.707dup p.N236Kfs*5 | Frame Shift Ins (INS) | VAF 23/100 reads (23%) | catalogued as rs751748506; called by mutect2, varscan2
- SRP68 | c.1561C>T p.R521W | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs775156164, COSV57165031; called by muse, mutect2, varscan2
- SRP68 | c.1165T>C p.S389P | Missense Mutation (SNP) | VAF 36/236 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.461); catalogued as COSV57165046; called by muse, mutect2, varscan2
- SRRT | c.445A>G p.M149V | Missense Mutation (SNP) | VAF 54/197 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV100730407; called by muse, mutect2, varscan2
- SSRP1 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs748483435, COSV53479039; called by muse, mutect2, varscan2
- ST3GAL1 | c.572A>G p.Y191C | Missense Mutation (SNP) | VAF 15/262 reads (6%) | PolyPhen probably damaging (1); catalogued as COSV60617090; called by muse, mutect2
- STAC | c.701T>C p.V234A | Missense Mutation (SNP) | VAF 47/280 reads (17%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV56219004; called by muse, mutect2, varscan2
- STAT5B | c.1749dup p.H584Tfs*8 | Frame Shift Ins (INS) | VAF 46/140 reads (33%) | catalogued as rs1202978138; called by mutect2, varscan2
- STK26 | c.701del p.N234Tfs*22 | Frame Shift Del (DEL) | VAF 73/310 reads (24%) | catalogued as COSV100688844; called by mutect2, pindel, varscan2
- STK32B | c.769G>C p.A257P | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.427); catalogued as COSV51515766; called by muse, mutect2, varscan2
- STK33 | c.438del p.V147* | Frame Shift Del (DEL) | VAF 198/1020 reads (19%) | catalogued as rs1485973228; called by mutect2, pindel, varscan2
- STN1 | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.47); catalogued as rs780655414, COSV56546283, COSV99830345; called by muse, mutect2, varscan2
- SULT1E1 | c.763A>G p.M255V | Missense Mutation (SNP) | VAF 113/468 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1271614778, COSV56949048; called by muse, mutect2, varscan2
- SUN3 | c.991A>G p.N331D | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV52054512; called by muse, mutect2, varscan2
- SUV39H1 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs782300985, COSV61921445; called by muse, mutect2
- SYNE1 | c.3926G>A p.R1309Q (on ENST00000367255 / NM_182961.4; = p.R1316Q on NM_033071.3) | Missense Mutation (SNP) | VAF 49/243 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1376716993, COSV55117644; called by muse, mutect2, varscan2
- SYNPO | c.1736G>T p.R579M (on ENST00000394243 / NM_001166208.2; = p.R335M on NM_007286.6) | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56943508; called by muse, mutect2, varscan2
- SYNPO2L | c.904C>T p.R302W (on ENST00000394810 / NM_001114133.3; = p.R78W on NM_024875.5) | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1276581493, COSV65737791; called by muse, mutect2
- SYT3 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs754832010, COSV58898266; called by muse, mutect2, varscan2
- TACC2 | c.2347del p.Q783Rfs*32 | Frame Shift Del (DEL) | VAF 21/84 reads (25%) | catalogued as rs750901207; called by mutect2, pindel, varscan2
- TAF1 | c.1735C>T p.R579W (on ENST00000373790 / NM_138923.4; = p.R600W on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/347 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs1234786163, COSV99335953; called by muse, mutect2, varscan2
- TANC2 | c.3859C>T p.R1287W | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs372803024; called by muse, mutect2, varscan2
- TAPBPL | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs774541786, COSV56947425; called by muse, mutect2, varscan2
- TAS2R38 | c.489dup p.S164* | Frame Shift Ins (INS) | VAF 27/117 reads (23%) | catalogued as rs1471160800; called by mutect2, pindel, varscan2
- TBC1D14 | c.1597C>T p.L533F | Missense Mutation (SNP) | VAF 12/376 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV68985881; called by muse, mutect2
- TBC1D15 | c.1904T>C p.V635A | Missense Mutation (SNP) | VAF 91/408 reads (22%) | SIFT tolerated (0.75); PolyPhen benign (0.049); catalogued as COSV59853397; called by muse, mutect2, varscan2
- TBC1D22A | c.96dup p.F33Lfs*2 | Frame Shift Ins (INS) | VAF 64/239 reads (27%) | catalogued as rs771822190; called by mutect2, varscan2
- TBCD | c.2582C>T p.T861M | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as rs370658754; called by muse, mutect2, varscan2
- TBR1 | c.1934C>T p.T645M | Missense Mutation (SNP) | VAF 53/268 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV67419343; called by muse, mutect2, varscan2
- TBX10 | c.291del p.F98Sfs*3 | Frame Shift Del (DEL) | VAF 26/98 reads (27%) | catalogued as rs748952707, COSV56876494; called by mutect2, varscan2
- TCF7L2 | c.598del p.L200Sfs*25 (on ENST00000355995 / NM_001367943.1; = p.L177Sfs*25 on NM_030756.5) | Frame Shift Del (DEL) | VAF 39/200 reads (20%) | catalogued as rs778855667; called by mutect2, pindel, varscan2
- TENM3 | c.6748del p.Y2250Mfs*4 | Frame Shift Del (DEL) | VAF 56/277 reads (20%) | catalogued as COSV101305550; called by mutect2, pindel, varscan2
- TENT4A | c.2347C>T p.R783W | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1277058984, COSV50102759, COSV50103116; called by muse, mutect2
- TENT5B | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV56694111; called by muse, mutect2, varscan2
- TEP1 | c.5566del p.V1856Lfs*45 | Frame Shift Del (DEL) | VAF 25/133 reads (19%) | catalogued as rs746695887; called by mutect2, pindel, varscan2
- TET1 | c.1441T>C p.S481P | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as COSV65389995; called by muse, mutect2, varscan2
- TEX14 | c.1204G>A p.E402K (on ENST00000240361 / NM_001201457.2; = p.E396K on NM_031272.5) | Missense Mutation (SNP) | VAF 64/287 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780108222, COSV53612664; called by muse, mutect2, varscan2
- TEX15 | c.7892C>T p.T2631I (on ENST00000256246; = p.T3014I on NM_001350162.2) | Missense Mutation (SNP) | VAF 112/546 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.303); catalogued as rs780433630, COSV56354883; called by muse, mutect2, varscan2
- TGM2 | c.742G>A p.G248S | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63931770; called by muse, mutect2, varscan2
- THEMIS2 | c.863G>T p.R288M | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV61078502; called by muse, mutect2
- THNSL2 | c.1417C>T p.R473* | Nonsense Mutation (SNP) | VAF 32/154 reads (21%) | catalogued as rs950597864, COSV59085123; called by muse, mutect2, varscan2
- TIMELESS | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs781372283, COSV57515671; called by muse, mutect2
- TJAP1 | c.817G>A p.D273N (on ENST00000372445 / NM_001146016.1; = p.D263N on NM_080604.3) | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV52504109; called by muse, mutect2, varscan2
- TMC6 | c.1951G>A p.V651I | Missense Mutation (SNP) | VAF 56/273 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as rs746180217, COSV59811133; called by muse, mutect2, varscan2
- TMEM143 | c.124del p.R42Gfs*45 | Frame Shift Del (DEL) | VAF 36/158 reads (23%) | catalogued as rs762159291, COSV53158530; called by mutect2, varscan2
- TMEM17 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 23/218 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs561991904, COSV59023354; called by muse, mutect2, varscan2
- TMEM183A | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 34/1007 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.091); catalogued as rs760661763, COSV100923318; called by muse, mutect2
- TMEM200A | c.356A>G p.H119R | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as rs780462355, COSV51660477; called by muse, mutect2, varscan2
- TMEM205 | c.370C>T p.R124* | Nonsense Mutation (SNP) | VAF 43/183 reads (23%) | catalogued as rs564427057, COSV55791382, COSV55793130; called by muse, mutect2, varscan2
- TMEM39A | c.121A>G p.S41G | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as COSV59901636; called by muse, mutect2, varscan2
- TMPRSS15 | c.2325dup p.L776Tfs*15 | Frame Shift Ins (INS) | VAF 34/170 reads (20%) | catalogued as rs749950017; called by mutect2, varscan2
- TMPRSS5 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 103/528 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as rs1220904630, COSV55426578; called by muse, mutect2
- TNFRSF10A | c.933_934del p.E312Afs*32 | Frame Shift Del (DEL) | VAF 57/329 reads (17%) | catalogued as COSV55327392; called by mutect2, pindel, varscan2
- TNFRSF13C | c.355G>A p.G119R | Missense Mutation (SNP) | VAF 15/189 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs778466279, COSV52170257; called by muse, mutect2
- TNRC6C | c.2031T>A p.S677R | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.513); catalogued as COSV56953655; called by muse, mutect2, varscan2
- TNS1 | c.2918del p.P973Rfs*13 | Frame Shift Del (DEL) | VAF 18/60 reads (30%) | catalogued as COSV50692006; called by mutect2, varscan2
- TOGARAM1 | c.2752A>G p.R918G | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV63895467; called by muse, mutect2, varscan2
- TOPBP1 | c.2851C>T p.P951S | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.09); catalogued as COSV53442555; called by muse, varscan2
- TRABD | c.532-2A>G p.X178_splice | Splice Site (SNP) | VAF 46/195 reads (24%) | catalogued as COSV57714305; called by muse, mutect2, varscan2
- TRADD | c.128G>T p.R43M | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV50758346; called by muse, mutect2
- TRAK1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs777442675, COSV59648509; called by muse, mutect2, varscan2
- TRDN | c.797A>G p.Q266R | Missense Mutation (SNP) | VAF 57/239 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs200068375; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRIM2 | c.776C>T p.A259V (on ENST00000437508; = p.A286V on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as COSV58639341; called by muse, mutect2, varscan2
- TRIM25 | c.1627G>A p.G543S | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866223501, COSV57544608, COSV57545107; called by muse, mutect2, varscan2
- TRIM75P | c.150G>T p.L50F | Missense Mutation (SNP) | VAF 64/280 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.24); catalogued as rs774683563; called by muse, mutect2, varscan2
- TRIO | c.6092del p.L2031* | Frame Shift Del (DEL) | VAF 15/141 reads (11%) | catalogued as rs752676391; called by mutect2, varscan2
- TRIO | c.7486C>T p.R2496* | Nonsense Mutation (SNP) | VAF 35/98 reads (36%) | catalogued as COSV59992640; called by muse, mutect2, varscan2
- TRIOBP | c.4152G>T p.E1384D | Missense Mutation (SNP) | VAF 16/269 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.018); catalogued as COSV100731172; called by muse, mutect2
- TRMT6 | c.458del p.K153Nfs*9 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as rs780358338; called by mutect2, varscan2
- TRPV2 | c.1927G>A p.A643T | Missense Mutation (SNP) | VAF 43/206 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58427265; called by muse, mutect2, varscan2
- TRUB2 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs549533426, COSV65760441; called by muse, mutect2, varscan2
- TSBP1 | c.671dup p.C225Lfs*18 (on ENST00000617061; = p.C228Lfs*18 on NM_006781.5) | Frame Shift Ins (INS) | VAF 32/222 reads (14%) | catalogued as rs759143582; called by mutect2, varscan2
- TSEN2 | c.722A>T p.Q241L | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV53191239; called by muse, mutect2, varscan2
- TSHZ2 | c.2213A>G p.D738G | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as COSV61591966; called by muse, mutect2, varscan2
- TSHZ3 | c.3034G>A p.E1012K | Missense Mutation (SNP) | VAF 114/462 reads (25%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.695); catalogued as rs376270774; called by muse, mutect2, varscan2
- TSNAXIP1 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs571319058, COSV54648286; called by muse, mutect2, varscan2
- TSPAN7 | c.516del p.S173Afs*4 | Frame Shift Del (DEL) | VAF 43/225 reads (19%) | catalogued as rs752121179, COSV54531581; called by mutect2, pindel, varscan2
- TSPYL6 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs372159200, COSV57811910; called by muse, mutect2, varscan2
- TTBK1 | c.220C>T p.L74F | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52497289; called by muse, mutect2, varscan2
- TTBK2 | c.1195A>G p.K399E | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51182298; called by muse, mutect2
- TTC12 | c.795del p.I266Lfs*4 | Frame Shift Del (DEL) | VAF 53/225 reads (24%) | catalogued as rs1555145313; called by mutect2, pindel, varscan2
- TTC14 | c.903dup p.Q302Tfs*15 | Frame Shift Ins (INS) | VAF 14/56 reads (25%) | catalogued as rs1560072646; called by mutect2, varscan2
- TTC19 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs910015274, COSV55424504; called by muse, mutect2, varscan2
- TTLL12 | c.1634C>T p.T545M | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.108); catalogued as rs138428335; called by muse, mutect2, varscan2
- TTLL5 | c.2890C>T p.R964* | Nonsense Mutation (SNP) | VAF 37/212 reads (17%) | catalogued as rs777359273, COSV54040766; called by muse, mutect2, varscan2
- TTN | c.99725G>A p.R33242H (on ENST00000591111; = p.R25818H on NM_003319.4) | Missense Mutation (SNP) | VAF 48/155 reads (31%) | PolyPhen probably damaging (0.998); catalogued as rs368063908, COSV59941149; called by muse, mutect2, varscan2
- TTN | c.98801G>A p.R32934H (on ENST00000591111; = p.R25510H on NM_003319.4) | Missense Mutation (SNP) | VAF 78/359 reads (22%) | PolyPhen probably damaging (0.982); catalogued as rs753392761, COSV60381995; called by muse, mutect2, varscan2
- TTN | c.74155C>T p.R24719C (on ENST00000591111; = p.R17295C on NM_003319.4) | Missense Mutation (SNP) | VAF 33/161 reads (20%) | PolyPhen probably damaging (0.998); catalogued as rs889825410, COSV60129938; called by muse, mutect2, varscan2
- TUBGCP3 | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 53/219 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs773635187, COSV56184764; called by muse, mutect2, varscan2
- TUT1 | c.1927C>T p.R643W | Missense Mutation (SNP) | VAF 82/370 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs761919342, COSV53471938; called by muse, mutect2, varscan2
- TXN2 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 59/323 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs776811065, COSV53397825; called by muse, mutect2, varscan2
- UBE2D2 | c.244G>A p.G82S | Missense Mutation (SNP) | VAF 118/468 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV54080718; called by muse, mutect2, varscan2
- UBE2K | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 42/165 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54693611; called by muse, mutect2, varscan2
- UBE3B | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs147402736; called by muse, mutect2, varscan2
- UBE3C | c.2281G>T p.G761C | Missense Mutation (SNP) | VAF 57/244 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61955856; called by muse, mutect2, varscan2
- UBQLN1 | c.1363T>C p.S455P | Missense Mutation (SNP) | VAF 48/193 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as COSV57409664; called by muse, mutect2, varscan2
- UBR4 | c.14899C>T p.R4967C | Missense Mutation (SNP) | VAF 17/336 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100920683; called by muse, mutect2
- ULK2 | c.2105C>T p.P702L | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs1022680609, COSV64444719; called by muse, mutect2, varscan2
- UNC79 | c.5048C>A p.P1683Q (on ENST00000393151 / NM_001346218.2; = p.P1506Q on NM_020818.5) | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.251); catalogued as COSV56375700, COSV56414071; called by muse, mutect2, varscan2
- UNC93B1 | c.446T>C p.F149S | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV99916564; called by muse, mutect2, varscan2
- USP20 | c.955C>T p.R319* | Nonsense Mutation (SNP) | VAF 41/141 reads (29%) | catalogued as COSV59619793; called by muse, mutect2, varscan2
- USP35 | c.1962dup p.T655Hfs*74 | Frame Shift Ins (INS) | VAF 30/137 reads (22%) | catalogued as rs764735138; called by mutect2, varscan2
- USP6 | c.3615del p.R1206Gfs*38 | Frame Shift Del (DEL) | VAF 34/305 reads (11%) | catalogued as rs764263657; called by mutect2, varscan2
- UVSSA | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs750867210, COSV66231093; called by muse, mutect2, varscan2
- VANGL2 | c.1327G>A p.A443T | Missense Mutation (SNP) | VAF 46/236 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs552247057, COSV63605561; called by muse, mutect2, varscan2
- VCL | c.1182G>A p.W394* | Nonsense Mutation (SNP) | VAF 27/144 reads (19%) | catalogued as COSV53015191; called by muse, mutect2, varscan2
- VDAC1 | c.802G>A p.V268I | Missense Mutation (SNP) | VAF 82/519 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs774989304, COSV51549154; called by muse, mutect2, varscan2
- VIRMA | c.2511G>T p.L837F | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.654); catalogued as COSV52591975; called by muse, mutect2
- VPS11 | c.310G>A p.A104T (on ENST00000620429; = p.A648T on NM_021729.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.04); catalogued as rs782051419, COSV100333762; called by muse, mutect2
- VSX2 | c.88A>G p.T30A | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.299); catalogued as rs1021777049, COSV56218648; called by muse, mutect2, varscan2
- VWA7 | c.2665G>A p.A889T | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as COSV65174222; called by muse, mutect2
- VWCE | c.866C>A p.P289H | Missense Mutation (SNP) | VAF 73/297 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57115812; called by muse, mutect2, varscan2
- WDFY3 | c.5899C>T p.R1967W | Missense Mutation (SNP) | VAF 54/277 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766875579, COSV55695997; called by muse, mutect2, varscan2
- WDFY3 | c.3645T>G p.D1215E | Missense Mutation (SNP) | VAF 74/450 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as COSV99885996; called by muse, varscan2
- WDTC1 | c.1861G>A p.V621M (on ENST00000319394 / NM_001276252.2; = p.V620M on NM_015023.5) | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV60087376; called by muse, mutect2, varscan2
- WNT3 | c.322+2T>C p.X108_splice | Splice Site (SNP) | VAF 58/331 reads (18%) | catalogued as COSV56647356, COSV99843412; called by muse, mutect2, varscan2
- WWOX | c.617T>C p.V206A | Missense Mutation (SNP) | VAF 50/290 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV68371610; called by muse, mutect2, varscan2
- XCR1 | c.40del p.Y14Tfs*33 | Frame Shift Del (DEL) | VAF 31/124 reads (25%) | catalogued as rs1158688440; called by mutect2, pindel, varscan2
- YEATS2 | c.2960C>T p.T987M | Missense Mutation (SNP) | VAF 53/220 reads (24%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs377227996, COSV59366890; called by muse, mutect2, varscan2
- YIPF4 | c.724A>G p.T242A | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV53215160; called by muse, mutect2, varscan2
- ZC3H4 | c.1529C>T p.P510L | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV53417656; called by muse, mutect2, varscan2
- ZC3HC1 | c.595C>A p.L199I | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.732); catalogued as COSV61300511; called by muse, mutect2, varscan2
- ZDHHC8 | c.1368del p.T459Rfs*177 | Frame Shift Del (DEL) | VAF 50/214 reads (23%) | catalogued as rs752072853; called by mutect2, pindel, varscan2
- ZFPM2 | c.129G>T p.E43D | Missense Mutation (SNP) | VAF 11/256 reads (4%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.956); catalogued as COSV68272945, COSV68277668; called by muse, mutect2
- ZFR2 | c.2612A>G p.Q871R | Missense Mutation (SNP) | VAF 55/268 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV53603880; called by muse, mutect2, varscan2
- ZHX2 | c.266A>T p.N89I | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV58717967; called by muse, mutect2, varscan2
- ZMYND8 | c.1105T>C p.Y369H (on ENST00000311275 / NM_001363741.2; = p.Y389H on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/398 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99521413; called by muse, mutect2
- ZNF124 | c.612A>C p.K204N (on ENST00000543802 / NM_001297568.1; = p.K142N on NM_003431.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as COSV61508060; called by muse, mutect2, varscan2
- ZNF16 | c.1609C>T p.R537* | Nonsense Mutation (SNP) | VAF 50/241 reads (21%) | catalogued as rs777992805, COSV52765889; called by muse, mutect2, varscan2
- ZNF221 | c.1306C>T p.R436* | Nonsense Mutation (SNP) | VAF 44/144 reads (31%) | catalogued as rs148293806; called by muse, mutect2, varscan2
- ZNF281 | c.374T>G p.V125G | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV54170142; called by muse, mutect2, varscan2
- ZNF322 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 83/510 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200129478, COSV70652198; called by muse, mutect2, varscan2
- ZNF35 | c.1468A>G p.T490A | Missense Mutation (SNP) | VAF 46/236 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); catalogued as COSV56077595; called by muse, mutect2, varscan2
- ZNF483 | c.25A>G p.K9E | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV58517405; called by muse, mutect2, varscan2
- ZNF536 | c.1637G>A p.R546H | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV62828022; called by muse, mutect2, varscan2
- ZNF547 | c.679C>T p.L227F | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.718); catalogued as COSV56582358; called by muse, mutect2, varscan2
- ZNF570 | c.908A>G p.E303G | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.816); catalogued as COSV100356317; called by muse, varscan2
412 further variants in this file (151 protein-altering or splice-affecting, 239 silent, 22 other) are not listed here.
